Somatic mutation profile of tumor specimen TCGA-DK-AA71-01A (aliquot TCGA-DK-AA71-01A-31D-A391-08) from TCGA case TCGA-DK-AA71, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 71.0 years (25,950 days).
Specimen TCGA-DK-AA71-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 34e1bf72-56e6-4789-a727-fae9300b1257.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DK-AA71-10A (Blood Derived Normal), aliquot TCGA-DK-AA71-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5a324c57-a8e9-48c2-aacc-553d8ff641b1

The open-access MAF lists 754 somatic variants for this specimen: 531 protein-altering or splice-affecting, 198 silent, 25 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 468, Silent 198, Nonsense Mutation 43, Intron 12, Splice Site 12, RNA 6, Splice Region 3, Frame Shift Del 3, 5'UTR 2, 3'Flank 2, 3'UTR 2, Nonstop Mutation 1.

Variants (750 of 754; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.*174A>G | 3'UTR (SNP) | VAF 86/145 reads (59%) | catalogued as rs121913485, CM960657, COSV53390174; ClinVar: likely pathogenic / uncertain significance / pathogenic; called by muse, mutect2, varscan2
- LZTR1 | c.742G>A p.G248R | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs869320686, CM154934, COSV53144758; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 35/54 reads (65%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA2 | c.3395G>C p.R1132T (on ENST00000614293; = p.R1102T on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as COSV99686627; called by muse, mutect2
- ABCB6 | c.25G>T p.E9* | Nonsense Mutation (SNP) | VAF 8/17 reads (47%) | catalogued as rs1159310240, COSV99521368; called by muse, mutect2, varscan2
- ABI2 | c.778G>A p.E260K (on ENST00000295851 / NM_001375719.1; = p.E254K on NM_005759.7 and 35 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.969); catalogued as COSV53692049; called by muse, mutect2, varscan2
- AC006059.2 | c.1907C>T p.S636L | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV59606914; called by muse, mutect2, varscan2
- ACSBG2 | c.29G>C p.G10A | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.007); catalogued as COSV53124932; called by muse, mutect2, varscan2
- ACSF2 | c.1304G>T p.R435I | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.666); catalogued as COSV51972452; called by muse, mutect2, varscan2
- ACSL5 | c.1771G>C p.D591H (on ENST00000354273; = p.D647H on NM_016234.3) | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as COSV61130634; called by muse, mutect2, varscan2
- ADAMTS10 | c.2494G>A p.A832T | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV54354894; called by muse, mutect2, varscan2
- ADAMTS4 | c.1471G>A p.D491N | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs765392088, COSV100917664, COSV63489979; called by muse, mutect2, varscan2
- ADAT1 | c.835C>T p.H279Y | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV57186603; called by muse, mutect2, varscan2
- ADGRB3 | c.2563C>T p.R855C | Missense Mutation (SNP) | VAF 51/64 reads (80%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs769780063, COSV53244844; called by muse, mutect2, varscan2
- ADGRL4 | c.2003C>A p.S668Y | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV100875565, COSV66061653, COSV66064361; called by muse, mutect2, varscan2
- ALAS2 | c.1157C>G p.S386C | Missense Mutation (SNP) | VAF 34/45 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58190529, COSV58191727; called by muse, mutect2, varscan2
- AMN | c.332C>G p.S111C | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.821); catalogued as COSV54486814; called by muse, mutect2, varscan2
- ANKRD11 | c.6628G>T p.E2210* | Nonsense Mutation (SNP) | VAF 10/15 reads (67%) | catalogued as rs1350625482, COSV99967931; called by muse, mutect2, varscan2
- ANKRD11 | c.3931C>T p.R1311* | Nonsense Mutation (SNP) | VAF 25/77 reads (32%) | catalogued as COSV56355766; called by muse, mutect2, varscan2
- ANKRD11 | c.2827G>C p.E943Q | Missense Mutation (SNP) | VAF 71/121 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.543); catalogued as COSV56360992; called by muse, mutect2, varscan2
- ANKRD11 | c.2431G>C p.D811H | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.635); catalogued as COSV56361004; called by muse, mutect2, varscan2
- ANKRD11 | c.1824G>C p.K608N | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT tolerated (0.23); PolyPhen benign (0.261); catalogued as COSV56361022; called by muse, mutect2, varscan2
- AOC1 | c.1804G>A p.D602N | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT tolerated (0.68); PolyPhen benign (0.006); catalogued as rs764018076, COSV62868577; called by muse, varscan2
- AOX1 | c.3776C>G p.S1259* | Nonsense Mutation (SNP) | VAF 15/59 reads (25%) | catalogued as COSV99613305; called by muse, mutect2, varscan2
- AP3D1 | c.2948C>T p.S983F | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as rs768412125, COSV61426482; called by muse, mutect2, varscan2
- ARAP3 | c.4094C>G p.S1365C | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV53350551, COSV99499187; called by muse, mutect2, varscan2
- ARHGEF11 | c.4015G>C p.E1339Q | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.398); catalogued as COSV59354480; called by muse, mutect2, varscan2
- ARHGEF2 | c.2563G>C p.E855Q (on ENST00000361247 / NM_001162383.2; = p.E827Q on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.351); catalogued as COSV58111109; called by muse, mutect2
- ARID1A | c.3254C>A p.S1085* | Nonsense Mutation (SNP) | VAF 9/40 reads (23%) | catalogued as COSV100249938, COSV61383854; called by muse, mutect2, varscan2
- ARMH4 | c.1316C>G p.S439C | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV50764511; called by muse, mutect2, varscan2
- ARNTL2 | c.571G>C p.E191Q | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV53824211, COSV53825834; called by muse, mutect2, varscan2
- ARSB | c.1168G>T p.E390* | Nonsense Mutation (SNP) | VAF 22/63 reads (35%) | catalogued as CM144020, COSV99364132; called by muse, mutect2, varscan2
- ATF7 | c.1472C>T p.S491F (on ENST00000548446 / NM_001366555.2; = p.S480F on NM_006856.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.276); catalogued as COSV60643811; called by muse, mutect2, varscan2
- ATF7 | c.391G>C p.D131H (on ENST00000548446 / NM_001366555.2; = p.D120H on NM_006856.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as COSV60643824; called by muse, mutect2, varscan2
- ATP12A | c.2212C>T p.P738S | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54516193; called by muse, mutect2, varscan2
- ATP1A4 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.159); catalogued as COSV63626496; called by muse, mutect2, varscan2
- ATP6V1A | c.1752G>A p.M584I | Missense Mutation (SNP) | VAF 50/97 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV56362252; called by muse, mutect2, varscan2
- BABAM2 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as rs1481096600, COSV59623327; called by muse, mutect2, varscan2
- BAZ1B | c.3343C>T p.P1115S | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV59991182; called by muse, mutect2, varscan2
- BAZ2B | c.6223G>A p.E2075K | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1464487006, COSV58600889; called by muse, mutect2, varscan2
- BID | c.609G>C p.K203N (on ENST00000317361 / NM_197966.2; = p.K157N on NM_001196.4) | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58006851, COSV58007446; called by muse, varscan2
- BLOC1S3 | c.43G>C p.E15Q | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV50065200; called by muse, varscan2
- BMP10 | c.906G>A p.M302I | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.21); PolyPhen benign (0.05); catalogued as COSV54895260; called by muse, mutect2, varscan2
- BMP8B | c.988T>G p.C330G | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62927739; called by muse, mutect2, varscan2
- BOC | c.1870G>A p.V624M | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1035075898, COSV56348795; called by muse, mutect2, varscan2
- BOLL | c.276+1del p.X92_splice | Splice Site (DEL) | VAF 25/78 reads (32%) | catalogued as rs1182450681; called by mutect2, pindel, varscan2
- BPIFB4 | c.442C>T p.H148Y | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV64951192; called by muse, mutect2, varscan2
- BRCA2 | c.6818G>A p.R2273K | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs587782174, COSV66453780; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRD4 | c.3796G>A p.E1266K | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.25); PolyPhen benign (0.118); catalogued as rs199833114, COSV99649654; called by muse, varscan2
- BRD4 | c.3547G>A p.E1183K | Missense Mutation (SNP) | VAF 52/93 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV54586250; called by muse, mutect2, varscan2
- BRDT | c.2657G>A p.G886E | Missense Mutation (SNP) | VAF 73/117 reads (62%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs746637899, COSV62865015; called by muse, mutect2, varscan2
- BRWD1 | c.329C>G p.S110C | Missense Mutation (SNP) | VAF 37/151 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58122490, COSV58122822; called by muse, mutect2, varscan2
- BSCL2 | c.156C>G p.F52L | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.887); catalogued as COSV53655041; called by muse, mutect2, varscan2
- BTAF1 | c.1486C>T p.L496F | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56431068, COSV99795941; called by muse, mutect2, varscan2
- BTBD2 | c.1478C>T p.T493M | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.807); catalogued as rs755413359, COSV55308840; called by muse, mutect2, varscan2
- BTNL9 | c.1399G>A p.D467N | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.769); catalogued as rs1295595400, COSV59795873; called by muse, mutect2, varscan2
- C12orf54 | c.97-1G>A p.X33_splice | Splice Site (SNP) | VAF 31/64 reads (48%) | catalogued as COSV58360303; called by muse, mutect2, varscan2
- C12orf54 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.043); catalogued as rs868088728, COSV58359933; called by muse, mutect2, varscan2
- C15orf39 | c.563G>T p.G188V | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.463); catalogued as COSV62296698; called by muse, mutect2, varscan2
- C16orf46 | c.1063C>G p.L355V | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as COSV55151151; called by muse, mutect2, varscan2
- C16orf46 | c.695C>G p.S232C | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV55151172; called by muse, mutect2, varscan2
- C4orf51 | c.391G>A p.D131N | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.833); catalogued as COSV71264274; called by muse, mutect2, varscan2
- CACNA1B | c.5014G>A p.E1672K | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as COSV53126087; called by muse, mutect2, varscan2
- CACNA1D | c.100C>G p.L34V | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV55447152; called by muse, mutect2, varscan2
- CADM1 | c.215C>G p.S72C | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV59010500; called by muse, mutect2, varscan2
- CADPS | c.1156G>C p.E386Q | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV51880089; called by muse, mutect2, varscan2
- CAMTA1 | c.3968C>G p.S1323C | Missense Mutation (SNP) | VAF 25/35 reads (71%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.219); catalogued as COSV57901079, COSV57918633; called by muse, mutect2, varscan2
- CASP1 | c.667G>A p.E223K (on ENST00000436863 / NM_033292.4; = p.E202K on NM_001223.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/121 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as rs756477465, COSV62056547; called by muse, mutect2, varscan2
- CATSPER2 | c.1033C>G p.Q345E | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV58660843; called by muse, mutect2, varscan2
- CCDC127 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 65/145 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.066); catalogued as COSV57256844; called by muse, mutect2, varscan2
- CCDC144A | c.327G>C p.K109N | Missense Mutation (SNP) | VAF 86/174 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.788); catalogued as COSV61403242; called by muse, mutect2, varscan2
- CCDC180 | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 33/59 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63830167; called by muse, mutect2, varscan2
- CCDC60 | c.243G>C p.K81N | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.787); catalogued as rs370380200; called by muse, mutect2, varscan2
- CCDC65 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as COSV57195629; called by muse, mutect2, varscan2
- CCDC80 | c.2428C>T p.L810= | Splice Region (SNP) | VAF 11/44 reads (25%) | catalogued as rs1189396763, COSV52816883; called by muse, mutect2, varscan2
- CCDC88B | c.1507G>A p.E503K | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.88); PolyPhen benign (0.015); catalogued as rs1052188170, COSV57266188; called by muse, mutect2, varscan2
- CD101 | c.2221G>A p.E741K | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.589); catalogued as COSV56718066; called by muse, mutect2, varscan2
- CD14 | c.370G>C p.E124Q | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.178); catalogued as COSV57370722; called by muse, mutect2, varscan2
- CD70 | c.350C>T p.S117F | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV55566201; called by muse, mutect2, varscan2
- CD72 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 61/80 reads (76%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.554); catalogued as COSV52411078; called by muse, mutect2, varscan2
- CDH10 | c.815-1G>A p.X272_splice | Splice Site (SNP) | VAF 6/26 reads (23%) | catalogued as COSV52580943; called by muse, mutect2, varscan2
- CDH13 | c.1783G>A p.D595N | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.997); catalogued as COSV51820224; called by muse, mutect2
- CDK15 | c.818G>A p.G273E (on ENST00000652192 / NM_001366386.2; = p.G222E on NM_139158.2) | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53631658; called by muse, mutect2, varscan2
- CDK7 | c.799G>A p.D267N | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1334449244, COSV56513488; called by muse, mutect2, varscan2
- CEACAM6 | c.977C>G p.S326* | Nonsense Mutation (SNP) | VAF 15/91 reads (16%) | catalogued as COSV99555358, COSV99555564; called by muse, mutect2, varscan2
- CELA2B | c.391G>A p.V131I | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.855); catalogued as rs769388813, COSV65545619; called by muse, mutect2, varscan2
- CELSR1 | c.2458G>C p.E820Q | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs1263577635, COSV53090204; called by muse, mutect2, varscan2
- CELSR1 | c.2294C>T p.S765F | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs137878225; called by mutect2, varscan2
- CENPF | c.1597C>T p.Q533* | Nonsense Mutation (SNP) | VAF 98/242 reads (40%) | catalogued as rs1174995496, COSV65276058; called by muse, mutect2, varscan2
- CENPJ | c.2162G>C p.R721T | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV67883433; called by muse, mutect2, varscan2
- CEP72 | c.1548G>C p.L516F | Missense Mutation (SNP) | VAF 64/179 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53792767; called by muse, mutect2, varscan2
- CFAP251 | c.1592C>G p.S531C | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.353); catalogued as COSV56610461; called by muse, mutect2, varscan2
- CFAP43 | c.2746G>A p.E916K | Missense Mutation (SNP) | VAF 43/87 reads (49%) | SIFT tolerated (0.27); PolyPhen benign (0.079); catalogued as COSV53377955; called by muse, mutect2, varscan2
- CFAP61 | c.3001G>C p.E1001Q | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV55629511, COSV55637932, COSV99844252; called by muse, mutect2, varscan2
- CFTR | c.4297G>C p.E1433Q | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as COSV50044057, COSV50053551; called by muse, mutect2, varscan2
- CHAD | c.306C>G p.I102M | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); catalogued as COSV51972445; called by muse, mutect2, varscan2
- CHD7 | c.6355G>A p.D2119N | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71110497; called by muse, mutect2, varscan2
- CLASP1 | c.1736C>G p.S579C | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as rs1372555730, COSV55324103; called by muse, mutect2, varscan2
- CLCN1 | c.898C>T p.R300W | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs368280521, CX942107; called by muse, mutect2, varscan2
- CLCNKB | c.1945G>C p.E649Q | Missense Mutation (SNP) | VAF 49/168 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.105); catalogued as rs1265392945, COSV65153276; called by muse, mutect2, varscan2
- CLIP4 | c.510G>C p.L170F | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60749167; called by muse, mutect2
- CLK3 | c.547C>T p.R183* (on ENST00000395066 / NM_001130028.1; = p.R35* on NM_003992.4) | Nonsense Mutation (SNP) | VAF 47/87 reads (54%) | catalogued as rs1459068786, COSV61413820; called by muse, mutect2, varscan2
- CLUAP1 | c.31G>T p.E11* | Nonsense Mutation (SNP) | VAF 38/73 reads (52%) | catalogued as COSV100489432; called by muse, mutect2, varscan2
- CNOT1 | c.4909C>T p.Q1637* | Nonsense Mutation (SNP) | VAF 52/93 reads (56%) | catalogued as COSV99798972; called by muse, mutect2, varscan2
- CNTNAP3 | c.3280G>C p.D1094H | Missense Mutation (SNP) | VAF 30/44 reads (68%) | SIFT deleterious (0.04); PolyPhen benign (0.145); catalogued as rs1202268769, COSV99903843; called by muse, mutect2, varscan2
- CNTROB | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 37/65 reads (57%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.831); catalogued as COSV58050205; called by muse, mutect2, varscan2
- COG5 | c.679C>G p.Q227E | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as COSV51751044; called by muse, mutect2, varscan2
- COL14A1 | c.3292G>C p.D1098H | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.824); catalogued as COSV52854488, COSV99920202; called by muse, mutect2, varscan2
- COL23A1 | c.934G>A p.D312N | Missense Mutation (SNP) | VAF 102/231 reads (44%) | SIFT tolerated (0.67); PolyPhen benign (0.274); catalogued as COSV66790665; called by muse, mutect2, varscan2
- COL2A1 | c.3583G>A p.E1195K | Missense Mutation (SNP) | VAF 60/113 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs1186663188, COSV61527447; called by muse, mutect2, varscan2
- COL4A5 | c.5035C>T p.Q1679* | Nonsense Mutation (SNP) | VAF 26/30 reads (87%) | catalogued as CM940312, COSV100086098; called by muse, mutect2, varscan2
- COL5A2 | c.1543C>T p.P515S | Missense Mutation (SNP) | VAF 102/192 reads (53%) | SIFT tolerated (0.31); PolyPhen benign (0.11); catalogued as COSV66409813; called by muse, mutect2, varscan2
- COL6A3 | c.1719G>C p.K573N | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV55089430; called by muse, mutect2, varscan2
- COPS8 | c.622G>C p.E208Q | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.537); catalogued as COSV62976259; called by muse, mutect2, varscan2
- CPD | c.2452G>A p.E818K | Missense Mutation (SNP) | VAF 79/181 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV56712888; called by muse, mutect2, varscan2
- CPLANE1 | c.8668G>A p.D2890N | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.109); catalogued as COSV57059989, COSV99950331; called by muse, mutect2, varscan2
- CPN1 | c.910G>C p.E304Q | Missense Mutation (SNP) | VAF 41/199 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV64942270; called by muse, mutect2, varscan2
- CPS1 | c.1688C>T p.P563L | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.529); catalogued as COSV51810138; called by muse, mutect2, varscan2
- CPS1 | c.2575G>A p.D859N | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs1559108770, COSV51810155; called by muse, varscan2
- CPSF6 | c.976C>T p.R326C | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.353); catalogued as rs1364684513, COSV57012505; called by muse, mutect2, varscan2
- CRISPLD2 | c.77C>G p.P26R | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as COSV52279387; called by muse, mutect2, varscan2
- CSGALNACT1 | c.1575G>C p.Q525H | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV59977641; called by muse, mutect2, varscan2
- CSMD2 | c.5767G>C p.E1923Q | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs147615570, COSV53912543, COSV99591827; called by muse, mutect2, varscan2
- CTCF | c.310G>T p.E104* | Nonsense Mutation (SNP) | VAF 30/68 reads (44%) | catalogued as COSV50504276, COSV99864041; called by muse, mutect2, varscan2
- CTCF | c.433G>C p.E145Q | Missense Mutation (SNP) | VAF 53/107 reads (50%) | SIFT tolerated (0.42); PolyPhen benign (0.054); catalogued as COSV50468840, COSV50496297; called by muse, mutect2, varscan2
- CTCF | c.792G>C p.K264N | Missense Mutation (SNP) | VAF 54/103 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV50468891; called by muse, mutect2, varscan2
- CTDP1 | c.864-1G>C p.X288_splice | Splice Site (SNP) | VAF 56/95 reads (59%) | catalogued as COSV50003292, COSV50005061; called by muse, mutect2, varscan2
- CTR9 | c.3178G>T p.D1060Y | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); catalogued as COSV63728595; called by muse, mutect2, varscan2
- CTSF | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as COSV59748653; called by muse, mutect2, varscan2
- CUBN | c.5144G>C p.R1715T | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.053); catalogued as COSV64715773; called by muse, mutect2, varscan2
- CXADR | c.820C>T p.H274Y | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.308); catalogued as COSV53029062; called by muse, mutect2, varscan2
- CXCR3 | c.99G>C p.E33D | Missense Mutation (SNP) | VAF 10/12 reads (83%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV65461932; called by muse, mutect2, varscan2
- CYB5B | c.254C>T p.S85F | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as COSV57174574; called by muse, mutect2, varscan2
- DAZL | c.752G>A p.S251N | Missense Mutation (SNP) | VAF 89/180 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.56); catalogued as COSV51712846, COSV99167465; called by muse, mutect2, varscan2
- DCAF1 | c.1099G>A p.D367N | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.987); catalogued as COSV60042880; called by muse, mutect2, varscan2
- DCAF12L1 | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 10/11 reads (91%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV64421788; called by muse, mutect2, varscan2
- DCDC1 | c.4915G>C p.E1639Q (on ENST00000597505 / NM_001367979.1; = p.E746Q on NM_020869.3) | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.876); catalogued as COSV57999265, COSV58001986; called by muse, mutect2, varscan2
- DENND2C | c.2713G>A p.E905K (on ENST00000393274 / NM_001256404.2; = p.E848K on NM_198459.4) | Missense Mutation (SNP) | VAF 94/208 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV67921767; called by muse, mutect2, varscan2
- DIAPH1 | c.3575A>T p.E1192V | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV53882455; called by muse, mutect2, varscan2
- DMTF1 | c.697G>C p.E233Q | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.608); catalogued as COSV58685274; called by muse, mutect2, varscan2
- DNAH8 | c.8698-1G>C p.X2900_splice | Splice Site (SNP) | VAF 22/30 reads (73%) | catalogued as COSV59445188; called by muse, mutect2, varscan2
- DNAH8 | c.8794G>C p.D2932H | Missense Mutation (SNP) | VAF 22/28 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV59445209; called by muse, mutect2, varscan2
- DNAJB11 | c.873G>C p.K291N | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.316); catalogued as COSV54002638; called by muse, mutect2, varscan2
- DOCK1 | c.2074C>T p.Q692* | Nonsense Mutation (SNP) | VAF 6/23 reads (26%) | catalogued as COSV99726240; called by muse, mutect2, varscan2
- DPP7 | c.301C>G p.L101V | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.473); catalogued as rs1258141605, COSV100857269; called by muse, mutect2, varscan2
- DSEL | c.2626G>A p.E876K | Missense Mutation (SNP) | VAF 103/190 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.423); catalogued as COSV59491546; called by muse, mutect2, varscan2
- DSPP | c.395C>T p.T132I | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.855); catalogued as COSV56810420; called by muse, mutect2, varscan2
- DST | c.2257G>T p.E753* (on ENST00000361203 / NM_001374722.1; = p.E427* on NM_001723.6) | Nonsense Mutation (SNP) | VAF 11/40 reads (28%) | catalogued as COSV99749435; called by muse, mutect2, varscan2
- DUSP16 | c.613C>T p.H205Y | Missense Mutation (SNP) | VAF 59/104 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV53807676; called by muse, mutect2, varscan2
- DVL2 | c.39G>T p.E13D | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.943); catalogued as COSV50035982; called by muse, mutect2, varscan2
- DYSF | c.2195C>G p.S732C | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.029); catalogued as COSV50330247; called by muse, mutect2, varscan2
- ECI2 | c.1130C>T p.S377L (on ENST00000380118 / NM_206836.3; = p.S347L on NM_006117.2) | Missense Mutation (SNP) | VAF 37/50 reads (74%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as rs1483127257, COSV60986495, COSV60988894; called by muse, mutect2, varscan2
- EFCAB6 | c.839G>A p.R280K | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1428554776, COSV53063315; called by muse, mutect2, varscan2
- EIF4G2 | c.552C>G p.V184= | Splice Region (SNP) | VAF 15/44 reads (34%) | catalogued as COSV60597070; called by muse, mutect2, varscan2
- EIF4G3 | c.3629C>G p.S1210* | Nonsense Mutation (SNP) | VAF 11/53 reads (21%) | catalogued as COSV99942807; called by muse, mutect2, varscan2
- EIF5B | c.1480G>A p.E494K | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs961035259, COSV56813058; called by muse, mutect2, varscan2
- EMILIN3 | c.917G>A p.R306Q | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs747522209, COSV60035601; called by muse, mutect2, varscan2
- ENPP5 | c.165G>A p.M55I | Missense Mutation (SNP) | VAF 29/37 reads (78%) | SIFT tolerated (0.9); PolyPhen benign (0.005); catalogued as COSV57908050; called by muse, mutect2, varscan2
- EP300 | c.1887C>G p.Y629* | Nonsense Mutation (SNP) | VAF 8/37 reads (22%) | catalogued as COSV99607000; called by muse, mutect2, varscan2
- EP300 | c.6564G>A p.M2188I | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as COSV54332737; called by muse, varscan2
- EPB41 | c.2345G>C p.G782A (on ENST00000343067 / NM_001166005.2; = p.G573A on NM_203342.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.141); catalogued as COSV58046703; called by muse, mutect2, varscan2
- EPRS1 | c.3204C>G p.I1068M | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100859407, COSV65098928; called by muse, mutect2, varscan2
- EPS8L2 | c.1189G>C p.E397Q | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV59347939; called by muse, mutect2, varscan2
- ERCC3 | c.958C>G p.Q320E | Missense Mutation (SNP) | VAF 76/327 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53427098; called by muse, mutect2, varscan2
- ERLEC1 | c.1195C>G p.H399D | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as rs754044293, COSV51751764; called by muse, mutect2, varscan2
- ETV4 | c.88G>T p.E30* | Nonsense Mutation (SNP) | VAF 7/19 reads (37%) | catalogued as rs776306922, COSV100081499, COSV60043769; called by muse, varscan2
- EVI2A | c.496C>G p.L166V | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV55986013; called by muse, mutect2, varscan2
- EXOC4 | c.345G>T p.W115C | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54098413; called by muse, mutect2, varscan2
- EXOSC2 | c.185G>C p.R62T | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs748977410, COSV64910595; called by muse, mutect2, varscan2
- EXT1 | c.1865G>C p.G622A | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.329); catalogued as CD022143, COSV65479528; called by muse, mutect2, varscan2
- EYA2 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 80/163 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57943180; called by muse, mutect2, varscan2
- FAM120A | c.1984C>T p.L662F | Missense Mutation (SNP) | VAF 47/100 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.921); catalogued as COSV52905021; called by muse, mutect2, varscan2
- FAM169A | c.1511C>G p.S504C | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.639); catalogued as COSV63063984; called by muse, mutect2, varscan2
- FAM234A | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 50/184 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.019); catalogued as COSV56994443; called by muse, mutect2, varscan2
- FAM234B | c.1637C>T p.S546L | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); catalogued as COSV99545256; called by muse, mutect2
- FAM81A | c.884G>C p.R295T | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as rs202139461, COSV99892718; called by muse, varscan2
- FARP2 | c.859G>C p.E287Q | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50871357; called by muse, mutect2, varscan2
- FBXL2 | c.504G>C p.Q168H | Missense Mutation (SNP) | VAF 46/77 reads (60%) | SIFT tolerated (0.13); PolyPhen benign (0.081); catalogued as COSV52138788; called by muse, mutect2, varscan2
- FCSK | c.995C>T p.S332L | Missense Mutation (SNP) | VAF 28/177 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as COSV55370829; called by muse, mutect2, varscan2
- FEM1C | c.1571G>C p.R524T | Missense Mutation (SNP) | VAF 38/170 reads (22%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.801); catalogued as COSV57231552; called by muse, mutect2, varscan2
- FGD5 | c.1208G>A p.G403E | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.014); catalogued as COSV53242746; called by muse, mutect2, varscan2
- FGF5 | c.281G>C p.R94T | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56890118; called by muse, mutect2, varscan2
- FHOD3 | c.504C>G p.I168M | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57163188, COSV57178930; called by muse, mutect2, varscan2
- FKBP4 | c.640G>C p.G214R | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV50008876, COSV50009093; called by muse, mutect2, varscan2
- FKBP4 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.21); catalogued as COSV50009096; called by muse, mutect2, varscan2
- FKBP4 | c.936G>C p.Q312H | Missense Mutation (SNP) | VAF 24/35 reads (69%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV50009102; called by muse, mutect2, varscan2
- FKBP4 | c.1032G>C p.K344N | Missense Mutation (SNP) | VAF 25/40 reads (63%) | SIFT deleterious (0.02); PolyPhen benign (0.432); catalogued as COSV50009110; called by muse, mutect2, varscan2
- FLG | c.3067G>A p.E1023K | Missense Mutation (SNP) | VAF 261/574 reads (45%) | SIFT tolerated (0.54); PolyPhen benign (0.071); catalogued as COSV64241849; called by muse, mutect2, varscan2
- FMN2 | c.2251G>A p.E751K | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as COSV100145962, COSV60430513; called by muse, mutect2, varscan2
- FNIP2 | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 56/99 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV52439863; called by muse, mutect2, varscan2
- FOLH1 | c.1443G>C p.L481= | Splice Region (SNP) | VAF 36/80 reads (45%) | catalogued as COSV57045915, COSV99922509; called by muse, mutect2, varscan2
- FRYL | c.3498G>C p.Q1166H | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV51947161; called by muse, mutect2, varscan2
- FUT9 | c.841A>G p.I281V | Missense Mutation (SNP) | VAF 44/56 reads (79%) | SIFT tolerated (0.75); PolyPhen benign (0.04); catalogued as rs1263768962, COSV56147008; called by muse, mutect2, varscan2
- FZD8 | c.1156G>T p.V386L | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.49); PolyPhen benign (0.208); catalogued as rs539148275, COSV65967891; called by muse, mutect2, varscan2
- GABPB1 | c.312G>C p.K104N | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.305); catalogued as COSV55014956; called by muse, mutect2, varscan2
- GAD1 | c.719C>T p.S240L | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV100713714; called by muse, mutect2
- GAPVD1 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52922994; called by muse, mutect2, varscan2
- GBA3 | c.553C>T p.H185Y | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV101545453; called by muse, mutect2, varscan2
- GEMIN2 | c.625C>G p.P209A | Missense Mutation (SNP) | VAF 42/72 reads (58%) | SIFT tolerated (0.17); PolyPhen benign (0.288); catalogued as COSV51628091; called by muse, mutect2, varscan2
- GIGYF1 | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.169); catalogued as COSV51941838; called by muse, mutect2, varscan2
- GPD1 | c.800G>A p.G267E | Missense Mutation (SNP) | VAF 67/136 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs866143632, COSV56548002; called by muse, mutect2, varscan2
- GRIP1 | c.2003G>C p.G668A (on ENST00000359742 / NM_001379345.1; = p.G616A on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 82/139 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as COSV54024272; called by muse, mutect2, varscan2
- GRK2 | c.1777G>A p.E593K | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.15); catalogued as COSV57752358; called by muse, mutect2
- GRM2 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.889); catalogued as COSV56584910; called by muse, mutect2, varscan2
- GSTO2 | c.694C>T p.Q232* | Nonsense Mutation (SNP) | VAF 51/101 reads (50%) | catalogued as rs371877418; called by muse, mutect2, varscan2
- GZMB | c.542A>G p.Y181C | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV53541342; called by muse, mutect2
- H2BC10 | c.194C>G p.S65C | Missense Mutation (SNP) | VAF 93/132 reads (70%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.435); catalogued as rs199638887, COSV59952998; called by muse, mutect2, varscan2
- H2BC21 | c.213C>G p.F71L | Missense Mutation (SNP) | VAF 10/218 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.404); catalogued as COSV100479607, COSV58611455; called by muse, mutect2
- H4C3 | c.148C>G p.L50V | Missense Mutation (SNP) | VAF 47/59 reads (80%) | SIFT deleterious (0.02); PolyPhen benign (0.112); catalogued as COSV58090557; called by muse, mutect2, varscan2
- HAT1 | c.353G>C p.G118A | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.2); catalogued as COSV51362643; called by muse, mutect2, varscan2
- HERC1 | c.13529G>A p.R4510Q | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV71245850, COSV71247823; called by muse, mutect2, varscan2
- HGFAC | c.91C>T p.R31W | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs200267403; called by muse, mutect2, varscan2
- HIRA | c.1900G>C p.E634Q | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.107); catalogued as COSV54274999; called by muse, mutect2, varscan2
- HIRIP3 | c.299C>T p.S100L | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.537); catalogued as rs1170988510, COSV54229943; called by muse, mutect2, varscan2
- HMGB1 | c.625G>T p.E209* | Nonsense Mutation (SNP) | VAF 22/50 reads (44%) | catalogued as COSV100360825; called by muse, mutect2, varscan2
- HMX2 | c.551C>G p.S184C | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs375924624, COSV60592771; called by muse, varscan2
- HNRNPA3 | c.486G>C p.Q162H | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV101182798; called by muse, mutect2, varscan2
- HNRNPA3 | c.656G>A p.G219E | Missense Mutation (SNP) | VAF 71/123 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as COSV66820727, COSV66820821; called by muse, mutect2, varscan2
- HNRNPC | c.467C>T p.S156L (on ENST00000420743; = p.S143L on NM_004500.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/85 reads (61%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV60145066; called by muse, mutect2, varscan2
- HNRNPUL1 | c.2054G>A p.R685K | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as COSV54562291; called by muse, mutect2, varscan2
- HOMEZ | c.1294G>C p.D432H | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as rs1461208457, COSV62536976; called by muse, mutect2, varscan2
- HOMEZ | c.514C>G p.L172V | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0.172); catalogued as rs1056074764, COSV62536989; called by muse, mutect2, varscan2
- HOXC8 | c.102G>C p.R34S | Missense Mutation (SNP) | VAF 76/311 reads (24%) | SIFT tolerated (0.66); PolyPhen benign (0.214); catalogued as rs1234080988, COSV50001310; called by muse, mutect2, varscan2
- HOXC8 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 96/398 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs749816109, COSV50001325; called by muse, varscan2
- HOXC8 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV50001354; called by muse, mutect2, varscan2
- HS6ST3 | c.666C>G p.I222M | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.673); catalogued as rs771767570, COSV100939891; called by muse, varscan2
- HSP90AA1 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 12/20 reads (60%) | PolyPhen benign (0.031); catalogued as COSV54472188; called by muse, mutect2, varscan2
- HSP90B1 | c.2209G>A p.D737N | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.166); catalogued as COSV55355381; called by muse, mutect2, varscan2
- HSPA4L | c.166-1G>C p.X56_splice | Splice Site (SNP) | VAF 30/59 reads (51%) | catalogued as rs1278224195, COSV56545539; called by muse, mutect2, varscan2
- HTT | c.9336C>G p.F3112L | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100750243; called by muse, varscan2
- IARS2 | c.1976G>A p.G659E | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.538); catalogued as COSV56959736; called by muse, mutect2, varscan2
- IKBKB | c.945G>C p.L315F | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.135); catalogued as COSV60597351; called by muse, mutect2, varscan2
- IL18R1 | c.1529C>T p.S510L | Missense Mutation (SNP) | VAF 40/77 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.534); catalogued as rs746971974, COSV52124588; called by muse, mutect2, varscan2
- IL4I1 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as rs1294836600, COSV55578577; called by muse, mutect2, varscan2
- INAVA | c.1179G>C p.E393D | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.211); catalogued as rs1208115459, COSV66257146, COSV66257227; called by muse, mutect2, varscan2
- INTS13 | c.827C>G p.S276C | Missense Mutation (SNP) | VAF 53/103 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53902643; called by muse, mutect2, varscan2
- IPPK | c.433C>G p.P145A | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55333724; called by muse, mutect2, varscan2
- IRAK3 | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 61/102 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs765849164, COSV54161163, COSV54161811; called by muse, mutect2, varscan2
- ITIH2 | c.2332G>A p.E778K | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as rs1464642474, COSV64433163; called by muse, mutect2, varscan2
- ITPKB | c.1648C>G p.Q550E | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs764323520, COSV55261863; called by muse, mutect2, varscan2
- ITPR2 | c.5704G>A p.E1902K | Missense Mutation (SNP) | VAF 112/222 reads (50%) | SIFT tolerated (0.47); PolyPhen benign (0.021); catalogued as COSV67264919; called by muse, mutect2, varscan2
- IVNS1ABP | c.925G>A p.D309N | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62251061; called by muse, mutect2, varscan2
- JAK3 | c.1255-1G>A p.X419_splice | Splice Site (SNP) | VAF 5/8 reads (63%) | catalogued as rs1315983507, COSV101512862; called by muse, mutect2, varscan2
- KCND3 | c.1515C>G p.I505M | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as COSV56180917; called by muse, mutect2
- KCNF1 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.6); PolyPhen benign (0.052); catalogued as rs773536391, COSV54462309, COSV54464047; called by muse, mutect2, varscan2
- KCNH6 | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59003386; called by muse, mutect2, varscan2
- KDM3B | c.5104G>A p.E1702K | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1450717762, COSV58690759; called by muse, mutect2, varscan2
- KDM5C | c.3893C>G p.S1298C | Missense Mutation (SNP) | VAF 16/21 reads (76%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV64765001; called by muse, mutect2, varscan2
- KIAA1586 | c.127C>G p.L43V | Missense Mutation (SNP) | VAF 106/134 reads (79%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.978); catalogued as COSV66056630; called by muse, mutect2, varscan2
- KIDINS220 | c.1936C>T p.Q646* | Nonsense Mutation (SNP) | VAF 38/134 reads (28%) | catalogued as COSV56752439; called by muse, mutect2, varscan2
- KIDINS220 | c.1510C>T p.L504F | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as COSV56753455; called by muse, mutect2, varscan2
- KIF16B | c.1145G>A p.R382K | Missense Mutation (SNP) | VAF 86/214 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.299); catalogued as COSV61706207; called by muse, varscan2
- KIF26B | c.4645G>C p.E1549Q | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.53); PolyPhen benign (0.1); catalogued as rs1371470611, COSV100831456; called by muse, mutect2, varscan2
- KIF3C | c.1803G>C p.E601D | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV99266901; called by muse, mutect2
- KIF5A | c.2035G>A p.E679K | Missense Mutation (SNP) | VAF 99/159 reads (62%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs1191059574, COSV54054559; called by muse, mutect2, varscan2
- KLF5 | c.1252G>A p.D418N | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV66614445, COSV66614565; called by muse, mutect2, varscan2
- KLHDC4 | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs374624924, COSV54505805; called by muse, mutect2, varscan2
- KMT2D | c.15016G>T p.E5006* | Nonsense Mutation (SNP) | VAF 12/66 reads (18%) | catalogued as COSV99976473; called by muse, mutect2, varscan2
- KNL1 | c.6244G>C p.E2082Q (on ENST00000346991 / NM_170589.5; = p.E2056Q on NM_144508.5) | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV61154847; called by muse, mutect2, varscan2
- KRT9 | c.1790G>T p.G597V | Missense Mutation (SNP) | VAF 11/29 reads (38%) | PolyPhen possibly damaging (0.808); catalogued as COSV55853098; called by muse, mutect2, varscan2
- KRTAP11-1 | c.17C>G p.S6C | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.966); catalogued as rs148141061; called by muse, mutect2, varscan2
- LAMA3 | c.9949G>A p.E3317K (on ENST00000313654 / NM_198129.4; = p.E1708K on NM_000227.6) | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.81); PolyPhen benign (0.011); catalogued as COSV52534723; called by muse, mutect2, varscan2
- LAMB3 | c.2449C>T p.R817C | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.118); catalogued as rs1455380874, COSV61916910; called by muse, mutect2, varscan2
- LAP3 | c.1537C>T p.R513C | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as rs898043815, COSV56899750; called by muse, mutect2, varscan2
- LARS2 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 39/68 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs759498312, COSV55527631; called by muse, mutect2, varscan2
- LATS2 | c.192G>A p.M64I | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs748445519, COSV66875660; called by muse, mutect2, varscan2
- LBR | c.296C>T p.S99F | Missense Mutation (SNP) | VAF 46/96 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV55288937; called by muse, mutect2, varscan2
- LCAT | c.746C>T p.S249L | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as CM145222, COSV99862776; called by muse, mutect2, varscan2
- LEPR | c.2015C>G p.S672* | Nonsense Mutation (SNP) | VAF 16/53 reads (30%) | catalogued as COSV100756156, COSV60750413, COSV60754162; called by muse, mutect2, varscan2
- LIMD1 | c.1862G>C p.R621T | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV56267342; called by muse, mutect2, varscan2
- LIMK1 | c.627G>A p.M209I | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs182322108, COSV60281472; called by muse, mutect2, varscan2
- LONP1 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.011); catalogued as COSV62261685; called by muse, mutect2, varscan2
- LPAR6 | c.948C>A p.F316L | Missense Mutation (SNP) | VAF 38/72 reads (53%) | SIFT tolerated (0.65); PolyPhen benign (0.039); catalogued as COSV57303361, COSV57307458, COSV99926504; called by muse, mutect2, varscan2
- LRCH3 | c.525G>C p.L175F | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1246910880, COSV58392027; called by muse, mutect2, varscan2
- LRIG1 | c.542G>T p.G181V | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56239993, COSV56240036; called by muse, mutect2, varscan2
- LRIT3 | c.1012G>T p.E338* | Nonsense Mutation (SNP) | VAF 44/144 reads (31%) | catalogued as COSV100015723; called by muse, mutect2, varscan2
- LRIT3 | c.1462G>C p.E488Q | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.173); catalogued as COSV59985308; called by muse, mutect2
- LRP8 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV60098431; called by muse, mutect2, varscan2
- LRRC36 | c.79G>C p.E27Q | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as rs911637078, COSV61717428; called by muse, mutect2, varscan2
- LRRIQ1 | c.4465A>T p.S1489C | Missense Mutation (SNP) | VAF 73/199 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV67830821; called by muse, mutect2, varscan2
- LRSAM1 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.98); catalogued as COSV55940065; called by muse, mutect2, varscan2
- LTK | c.1906G>T p.E636* | Nonsense Mutation (SNP) | VAF 12/41 reads (29%) | catalogued as COSV53027770, COSV99540478; called by muse, mutect2, varscan2
- LYPLA2 | c.291G>C p.E97D | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV100994869, COSV65720668; called by muse, mutect2
- MACF1 | c.3154G>A p.E1052K | Missense Mutation (SNP) | VAF 16/28 reads (57%) | catalogued as COSV58373607; called by muse, mutect2, varscan2
- MACF1 | c.9109G>A p.E3037K | Missense Mutation (SNP) | VAF 21/71 reads (30%) | catalogued as COSV57121205; called by muse, mutect2, varscan2
- MAGED2 | c.1462G>A p.E488K | Missense Mutation (SNP) | VAF 26/33 reads (79%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.593); catalogued as rs779634966, COSV54497890; called by muse, mutect2, varscan2
- MAGI3 | c.3688C>T p.Q1230* | Nonsense Mutation (SNP) | VAF 30/96 reads (31%) | catalogued as COSV100287733; called by muse, mutect2, varscan2
- MAN2A1 | c.760G>A p.D254N | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54851612; called by muse, mutect2, varscan2
- MAP3K4 | c.846C>A p.F282L | Missense Mutation (SNP) | VAF 45/58 reads (78%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV62333592; called by muse, mutect2, varscan2
- MAP3K6 | c.2086C>G p.L696V | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV62888483; called by muse, mutect2, varscan2
- MAPK10 | c.800C>T p.A267V (on ENST00000359221 / NM_001351625.2; = p.A305V on NM_002753.5) | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.221); catalogued as rs866305399, COSV60379968; called by muse, mutect2, varscan2
- MAPK8IP3 | c.352G>C p.E118Q | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as COSV51720291; called by muse, mutect2, varscan2
- MARCHF10 | c.968C>T p.S323L | Missense Mutation (SNP) | VAF 127/329 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs1318866560, COSV60887220; called by muse, mutect2, varscan2
- MED1 | c.1141C>G p.P381A | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV56124903; called by muse, mutect2, varscan2
- MELTF | c.412G>A p.V138M | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV56381291; called by muse, mutect2, varscan2
- METTL2A | c.956G>A p.G319E | Missense Mutation (SNP) | VAF 123/290 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61044517; called by muse, mutect2, varscan2
- MFGE8 | c.652C>G p.L218V | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.365); catalogued as rs1385592846, COSV51556149; called by muse, mutect2, varscan2
- MICAL1 | c.952C>T p.R318W | Missense Mutation (SNP) | VAF 15/19 reads (79%) | SIFT deleterious (0.02); PolyPhen benign (0.328); catalogued as rs774702048, COSV62192991; called by muse, mutect2, varscan2
- MISP | c.1475C>T p.P492L | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs112598403, COSV53120135; called by muse, mutect2, varscan2
- MMD2 | c.333C>G p.I111M | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68660622; called by muse, mutect2, varscan2
- MORN1 | c.993G>C p.L331F | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV66002970; called by muse, mutect2, varscan2
- MPHOSPH8 | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.395); catalogued as COSV64055612; called by muse, mutect2, varscan2
- MPL | c.166G>C p.E56Q | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.649); catalogued as COSV65244831; called by muse, mutect2, varscan2
- MRE11 | c.1673C>T p.S558F | Missense Mutation (SNP) | VAF 56/115 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV60575751; called by muse, mutect2, varscan2
- MTERF1 | c.679C>T p.H227Y | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as rs761977328, COSV61098269; called by muse, mutect2, varscan2
- MTERF1 | c.187C>G p.H63D | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs1343573526, COSV61098277; called by muse, mutect2, varscan2
- MTF2 | c.58C>T p.R20* | Nonsense Mutation (SNP) | VAF 13/69 reads (19%) | catalogued as COSV64769577; called by muse, mutect2, varscan2
- MTMR1 | c.239C>T p.S80F | Missense Mutation (SNP) | VAF 51/57 reads (89%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.553); catalogued as COSV64898013; called by muse, mutect2, varscan2
- MTREX | c.754G>C p.D252H | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57926019; called by muse, mutect2, varscan2
- MTRF1 | c.917G>A p.R306Q | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.241); catalogued as rs369215867; called by muse, mutect2, varscan2
- MUC16 | c.31934C>T p.S10645L | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.006); catalogued as COSV67465943; called by muse, mutect2
- MYBPC3 | c.2527G>C p.E843Q | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as CM043544, COSV57027598; called by muse, mutect2, varscan2
- MYH10 | c.3122-1G>A p.X1041_splice | Splice Site (SNP) | VAF 27/91 reads (30%) | catalogued as COSV52601159, COSV52612169; called by muse, mutect2, varscan2
- MYH3 | c.3366G>C p.E1122D | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.433); catalogued as COSV56864952; called by muse, mutect2, varscan2
- MYO1A | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 57/87 reads (66%) | SIFT tolerated (0.09); PolyPhen benign (0.153); catalogued as COSV55653973; called by muse, mutect2, varscan2
- MYO1A | c.924G>C p.L308F | Missense Mutation (SNP) | VAF 89/144 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55653983; called by muse, mutect2, varscan2
- MYO1A | c.890G>A p.R297K | Missense Mutation (SNP) | VAF 32/52 reads (62%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV55653995; called by muse, mutect2, varscan2
- MYO1B | c.563-1G>A p.X188_splice | Splice Site (SNP) | VAF 67/132 reads (51%) | catalogued as COSV58430984; called by muse, mutect2, varscan2
- MYSM1 | c.1669G>A p.D557N | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.857); catalogued as COSV68977485; called by muse, mutect2, varscan2
- NAGPA | c.439G>C p.E147Q | Missense Mutation (SNP) | VAF 17/24 reads (71%) | PolyPhen benign (0.154); catalogued as COSV100392778, COSV100393025; called by muse, mutect2, varscan2
- NANP | c.130G>C p.E44Q | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.246); catalogued as COSV59160176; called by muse, mutect2, varscan2
- NARF | c.769G>A p.G257S | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.962); catalogued as COSV59111754; called by muse, mutect2, varscan2
- NAV2 | c.4871C>G p.S1624* (on ENST00000396087 / NM_001244963.2; = p.S1601* on NM_145117.5) | Nonsense Mutation (SNP) | VAF 18/29 reads (62%) | catalogued as COSV60664176; called by muse, mutect2
- NEB | c.19911C>G p.I6637M | Missense Mutation (SNP) | VAF 67/121 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV51405262; called by muse, mutect2, varscan2
- NECTIN2 | c.1342G>C p.E448Q | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.601); catalogued as rs933325464, COSV52977413; called by muse, mutect2, varscan2
- NEU3 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV53636623; called by muse, mutect2, varscan2
- NFRKB | c.3779G>A p.R1260H (on ENST00000446488 / NM_001143835.2; = p.R1285H on NM_006165.3) | Missense Mutation (SNP) | VAF 33/60 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs376939410; called by muse, mutect2, varscan2
- NHLRC2 | c.1541G>A p.G514E | Missense Mutation (SNP) | VAF 42/171 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV65174904; called by muse, mutect2, varscan2
- NIBAN1 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 134/273 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs1355419670, COSV62284756; called by muse, mutect2, varscan2
- NOMO1 | c.1140G>C p.Q380H | Missense Mutation (SNP) | VAF 60/138 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV99814119; called by muse, mutect2, varscan2
- NOP16 | c.287-1G>C p.X96_splice | Splice Site (SNP) | VAF 48/102 reads (47%) | catalogued as COSV51257631; called by muse, mutect2, varscan2
- NPAS2 | c.1844G>C p.R615T | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.276); catalogued as COSV59557776; called by muse, mutect2, varscan2
- NUAK1 | c.328C>G p.L110V | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.922); catalogued as rs1345074497, COSV54603320; called by muse, mutect2, varscan2
- NUP160 | c.1129G>A p.E377K | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as COSV65854381; called by muse, mutect2, varscan2
- NXNL2 | c.195C>A p.F65L | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.047); catalogued as COSV65474446; called by muse, mutect2, varscan2
- NXPE4 | c.1437G>C p.E479D (on ENST00000375478 / NM_001077639.2; = p.E195D on NM_017678.3) | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.12); catalogued as COSV64943765; called by muse, mutect2, varscan2
- OR4A16 | c.773G>C p.R258T | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.913); catalogued as rs781461278, COSV59043108; called by muse, mutect2, varscan2
- OR52K2 | c.697C>G p.Q233E | Missense Mutation (SNP) | VAF 96/196 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.174); catalogued as COSV57834822, COSV57835398; called by muse, mutect2, varscan2
- OR52N5 | c.358G>C p.E120Q | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.725); catalogued as rs1341893088, COSV57698878, COSV57699126; called by muse, mutect2, varscan2
- OR7C2 | c.273G>C p.M91I | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV50180649; called by muse, mutect2, varscan2
- OSBP | c.455C>A p.S152Y | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55662598; called by muse, mutect2, varscan2
- OTULINL | c.342G>A p.M114I | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.961); catalogued as COSV57034508; called by muse, mutect2, varscan2
- PASD1 | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 56/60 reads (93%) | SIFT deleterious (0.04); PolyPhen benign (0.047); catalogued as COSV100949366, COSV64855294; called by muse, mutect2, varscan2
- PCDHB16 | c.1151C>T p.S384F | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.938); catalogued as COSV53362299; called by muse, mutect2, varscan2
- PCDHB8 | c.811G>C p.D271H | Missense Mutation (SNP) | VAF 78/378 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50767911; called by muse, mutect2, varscan2
- PCDHGC5 | c.2101G>T p.V701F | Missense Mutation (SNP) | VAF 61/147 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.24); catalogued as rs775712620, COSV52752144; called by muse, mutect2, varscan2
- PCM1 | c.3308C>T p.S1103L | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT tolerated (0.19); PolyPhen benign (0.395); catalogued as rs199506881, COSV61519836; called by muse, varscan2
- PEAK1 | c.4332G>C p.Q1444H | Missense Mutation (SNP) | VAF 65/120 reads (54%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV56935433; called by muse, mutect2, varscan2
- PEX10 | c.130G>C p.E44Q | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.033); catalogued as rs1430139842, COSV56580014; called by muse, mutect2, varscan2
- PFKM | c.1320C>G p.F440L | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56656681, COSV56657350; called by muse, mutect2, varscan2
- PGPEP1 | c.211G>C p.V71L | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as rs1317955674, COSV99416394; called by muse, varscan2
- PIAS3 | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV65171365; called by muse, mutect2, varscan2
- PIK3C2A | c.4370C>T p.S1457L | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.138); catalogued as COSV56402852, COSV56406146; called by muse, mutect2, varscan2
- PIK3R3 | c.691C>G p.H231D | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV53107279; called by muse, mutect2, varscan2
- PKHD1L1 | c.1822G>C p.D608H | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.868); catalogued as COSV65742955; called by muse, mutect2, varscan2
- PLCH2 | c.1340C>T p.S447L | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as COSV53942940; called by muse, mutect2, varscan2
- PLCL1 | c.1586C>T p.S529L | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV70822841; called by muse, mutect2, varscan2
- PLCL1 | c.2729C>T p.S910F | Missense Mutation (SNP) | VAF 101/438 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.496); catalogued as COSV104436641, COSV70831933, COSV70834255; called by muse, mutect2, varscan2
- PLCL2 | c.2452C>G p.Q818E (on ENST00000615277 / NM_001144382.2; = p.Q692E on NM_015184.5) | Missense Mutation (SNP) | VAF 56/101 reads (55%) | SIFT tolerated (0.1); PolyPhen benign (0.135); catalogued as rs141376640, COSV67622127, COSV67624350; called by muse, mutect2, varscan2
- PLEKHA7 | c.751C>G p.Q251E | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.174); catalogued as COSV63046180, COSV63048000; called by muse, mutect2, varscan2
- PLEKHG4 | c.1486C>T p.Q496* | Nonsense Mutation (SNP) | VAF 17/29 reads (59%) | catalogued as COSV100846418; called by muse, mutect2, varscan2
- PLK4 | c.2462C>T p.S821F | Missense Mutation (SNP) | VAF 49/184 reads (27%) | SIFT tolerated (0.71); PolyPhen benign (0.01); catalogued as COSV54637461; called by muse, mutect2, varscan2
- PLXNA4 | c.4100C>T p.S1367F | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as COSV58125896; called by muse, mutect2, varscan2
- PLXNC1 | c.3620A>C p.K1207T | Missense Mutation (SNP) | VAF 33/175 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.271); catalogued as COSV51575343; called by muse, mutect2
- POLQ | c.7597T>G p.F2533V | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV51752029; called by muse, mutect2, varscan2
- PPARG | c.244C>G p.P82A (on ENST00000287820 / NM_015869.5; = p.P52A on NM_005037.7) | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.001); catalogued as COSV55142457; called by muse, mutect2, varscan2
- PPP1R12B | c.2564C>T p.S855L | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.366); catalogued as COSV51784949; called by muse, mutect2, varscan2
- PRPF39 | c.1713G>C p.Q571H | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV53532473; called by muse, mutect2, varscan2
- PSMA4 | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 22/35 reads (63%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.848); catalogued as COSV50384663; called by muse, mutect2, varscan2
- PSMD4 | c.1133G>T p.*378Lext*11 | Nonstop Mutation (SNP) | VAF 25/62 reads (40%) | catalogued as COSV100924638; called by muse, mutect2, varscan2
- PSMF1 | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 63/170 reads (37%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV55674032; called by muse, mutect2, varscan2
- PTCH1 | c.3283G>C p.E1095Q | Missense Mutation (SNP) | VAF 41/65 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV59474549; called by muse, mutect2, varscan2
- PTGES3L-AARSD1 | c.589G>A p.D197N (on ENST00000421990 / NM_001136042.2; = p.D179N on NM_025267.3) | Missense Mutation (SNP) | VAF 58/122 reads (48%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as rs1225051076, COSV64182782; called by muse, mutect2, varscan2
- PTPRM | c.341T>C p.L114P | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59859092; called by muse, varscan2
- PTPRM | c.398C>G p.S133C | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as rs747982067, COSV59859123; called by muse, varscan2
- PTPRM | c.3145G>A p.E1049K | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.841); catalogued as COSV100160872, COSV59859138; called by muse, mutect2, varscan2
- RAB3A | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as rs377115900; called by muse, mutect2, varscan2
- RARG | c.866C>T p.S289F | Missense Mutation (SNP) | VAF 42/82 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58432896; called by muse, mutect2, varscan2
- RASAL1 | c.2306G>C p.R769T | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.015); catalogued as COSV55656013; called by muse, mutect2, varscan2
- RBL2 | c.1414C>T p.Q472* | Nonsense Mutation (SNP) | VAF 12/54 reads (22%) | catalogued as COSV50876113; called by muse, mutect2, varscan2
- RGR | c.655C>G p.L219V | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV63894017; called by muse, mutect2, varscan2
- RHOJ | c.415G>A p.D139N | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.344); catalogued as rs1465882891, COSV57458404; called by muse, mutect2, varscan2
- RIMS2 | c.490C>G p.Q164E | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.058); catalogued as COSV68113123, COSV68113271; called by muse, mutect2, varscan2
- RINT1 | c.109C>G p.L37V | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as COSV57558550; called by muse, mutect2, varscan2
- RMDN1 | c.476C>G p.S159* | Nonsense Mutation (SNP) | VAF 52/104 reads (50%) | catalogued as COSV99547013; called by muse, mutect2, varscan2
- RNASEL | c.628C>T p.L210F | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.027); catalogued as COSV62376830; called by muse, mutect2, varscan2
- RNF2 | c.85C>T p.Q29* | Nonsense Mutation (SNP) | VAF 67/167 reads (40%) | catalogued as COSV100835621; called by muse, mutect2, varscan2
- RNF4 | c.197C>G p.S66C | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.086); catalogued as COSV58641151; called by muse, mutect2, varscan2
- ROBO1 | c.193G>C p.D65H | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV101458219, COSV71394365; called by muse, mutect2, varscan2
- ROCK2 | c.2810C>G p.S937C | Missense Mutation (SNP) | VAF 57/92 reads (62%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.848); catalogued as COSV59957250; called by muse, mutect2, varscan2
- RPE65 | c.339G>C p.K113N | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV52012809; called by muse, mutect2, varscan2
- RPH3A | c.277G>A p.D93N (on ENST00000389385 / NM_001143854.2; = p.D89N on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.998); catalogued as rs763299292, COSV66991118; called by muse, mutect2, varscan2
- RPH3AL | c.591C>G p.I197M | Missense Mutation (SNP) | VAF 52/81 reads (64%) | SIFT tolerated (0.05); PolyPhen benign (0.129); catalogued as COSV58742512; called by muse, mutect2, varscan2
- RPP25L | c.407C>T p.P136L | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52407333; called by muse, mutect2, varscan2
- RPRD2 | c.229C>G p.L77V | Missense Mutation (SNP) | VAF 106/234 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.752); catalogued as COSV64816848; called by muse, mutect2, varscan2
- RRNAD1 | c.806G>C p.R269T | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); catalogued as COSV63928977; called by muse, mutect2, varscan2
- RYR2 | c.8666C>T p.A2889V | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV63685714; called by muse, mutect2, varscan2
- RYR2 | c.9937C>T p.Q3313* | Nonsense Mutation (SNP) | VAF 4/22 reads (18%) | catalogued as rs1290143904, COSV63694842; called by muse, mutect2
- SALL3 | c.162G>C p.E54D | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs1311001003, COSV101609901; called by muse, mutect2, varscan2
- SAMSN1 | c.692A>G p.K231R | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0.012); catalogued as COSV53471456; called by muse, mutect2, varscan2
- SARAF | c.352G>C p.E118Q | Missense Mutation (SNP) | VAF 45/210 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); catalogued as COSV56357400; called by muse, mutect2, varscan2
- SCUBE2 | c.277G>C p.E93Q | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.601); catalogued as COSV58542826; called by muse, mutect2, varscan2
- SEL1L | c.68C>T p.S23L | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.08); catalogued as rs769308341, COSV60920520; called by muse, mutect2, varscan2
- SERPINA4 | c.561G>C p.K187N | Missense Mutation (SNP) | VAF 44/141 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.511); catalogued as COSV54068826, COSV54069909; called by muse, mutect2, varscan2
- SERPINC1 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); catalogued as rs1363092061, CD002477, COSV62928844, COSV62929140; called by muse, mutect2, varscan2
- SERTAD2 | c.794C>G p.S265* | Nonsense Mutation (SNP) | VAF 25/54 reads (46%) | catalogued as COSV100512071; called by muse, mutect2, varscan2
- SF3B3 | c.1061G>C p.G354A | Missense Mutation (SNP) | VAF 61/112 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs148171005; called by muse, varscan2
- SHOX2 | c.736C>T p.Q246* (on ENST00000441443 / NM_006884.3; = p.Q270* on NM_003030.4) | Nonsense Mutation (SNP) | VAF 31/59 reads (53%) | catalogued as COSV101273725; called by muse, mutect2, varscan2
- SIPA1L3 | c.3889G>C p.E1297Q | Missense Mutation (SNP) | VAF 47/65 reads (72%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); catalogued as COSV55914218; called by muse, mutect2, varscan2
- SLC17A6 | c.1319G>A p.R440K | Missense Mutation (SNP) | VAF 54/108 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV54136459, COSV99581946; called by muse, mutect2, varscan2
- SLC17A7 | c.1259C>G p.S420C | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV55547720; called by muse, mutect2, varscan2
- SLC22A12 | c.642G>C p.M214I | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV60572163, COSV60572655; called by muse, mutect2, varscan2
- SLC24A1 | c.1535C>T p.S512F | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368393675; called by muse, mutect2, varscan2
- SLC25A34 | c.381C>G p.I127M | Missense Mutation (SNP) | VAF 28/44 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as COSV53817054; called by muse, mutect2, varscan2
- SLC41A2 | c.869C>G p.S290C | Missense Mutation (SNP) | VAF 85/155 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV51605012; called by muse, mutect2, varscan2
- SLC46A1 | c.267G>T p.M89I | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1555591052, COSV100398001; called by muse, mutect2, varscan2
- SLC7A1 | c.905T>G p.F302C | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV66330557; called by muse, mutect2, varscan2
- SLCO1A2 | c.1238C>T p.S413F | Missense Mutation (SNP) | VAF 60/127 reads (47%) | SIFT tolerated (0.42); PolyPhen benign (0.033); catalogued as rs1379534260, COSV56599737, COSV56602097; called by muse, mutect2, varscan2
- SLIT3 | c.4193G>C p.G1398A | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV60608371; called by muse, varscan2
- SLIT3 | c.4139G>C p.G1380A | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as rs1292153284, COSV60608382, COSV60608601; called by muse, varscan2
- SLIT3 | c.1662G>C p.K554N | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV60608393, COSV60634357; called by muse, mutect2, varscan2
- SLU7 | c.132A>T p.K44N | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV51787747; called by muse, mutect2, varscan2
- SMARCC1 | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 42/70 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV54380644; called by muse, mutect2, varscan2
- SMPDL3B | c.716C>T p.P239L | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs138724868; called by muse, mutect2, varscan2
- SNX2 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 91/211 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.439); catalogued as COSV65348331; called by muse, mutect2, varscan2
- SNX6 | c.848C>T p.S283L (on ENST00000652385; = p.S155L on NM_021249.5) | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.46); catalogued as COSV61918572; called by muse, mutect2, varscan2
- SOCS5 | c.1247C>T p.S416F | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1386239400, COSV60604932; called by muse, mutect2, varscan2
- SOX12 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61258832; called by muse, mutect2, varscan2
- SPPL2C | c.643C>T p.R215W | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.96); catalogued as rs763285754, COSV61292478; called by muse, mutect2, varscan2
- SPRYD3 | c.1293G>C p.E431D | Missense Mutation (SNP) | VAF 44/92 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100036809, COSV56853839; called by muse, mutect2, varscan2
- SPTBN4 | c.777T>A p.D259E | Missense Mutation (SNP) | VAF 40/68 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.108); catalogued as COSV58949422; called by muse, mutect2, varscan2
- SPTBN5 | c.2479C>G p.P827A | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.098); catalogued as COSV58020571; called by muse, mutect2, varscan2
- SRFBP1 | c.195G>A p.M65I | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as rs770116333, COSV59581729; called by muse, mutect2, varscan2
- STRN | c.1204C>T p.P402S | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.334); catalogued as COSV99814821; called by muse, mutect2
- SUCO | c.2185C>G p.L729V | Missense Mutation (SNP) | VAF 51/126 reads (40%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as rs757063370, COSV55265368; called by muse, mutect2, varscan2
- SULT1C2 | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.274); catalogued as COSV52264906; called by muse, mutect2, varscan2
- SUSD4 | c.1063G>T p.G355W | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1448765146, COSV100663433; called by muse, mutect2, varscan2
- SYCP1 | c.1741G>A p.E581K | Missense Mutation (SNP) | VAF 21/26 reads (81%) | SIFT tolerated (0.37); PolyPhen benign (0.011); catalogued as rs1414694209, COSV65697449; called by muse, mutect2, varscan2
- SYNE2 | c.4894G>A p.E1632K | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1481779851, COSV59951038; called by muse, mutect2, varscan2
- SYNM | c.1412C>T p.S471L | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs564598837, COSV60369795; called by muse, mutect2, varscan2
- TACSTD2 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as COSV64667085; called by muse, mutect2, varscan2
- TALDO1 | c.434C>T p.S145L | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs752130789, COSV59797588; called by muse, mutect2, varscan2
- TARS3 | c.886G>C p.E296Q | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.222); catalogued as COSV100254472, COSV60108103; called by muse, mutect2, varscan2
- TCF20 | c.1580C>T p.S527L | Missense Mutation (SNP) | VAF 60/225 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV59491207; called by muse, mutect2, varscan2
- TCF20 | c.13C>T p.R5W | Missense Mutation (SNP) | VAF 23/36 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59491235; called by muse, mutect2, varscan2
- TCP11L1 | c.1241C>T p.S414F | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.305); catalogued as COSV57515332; called by muse, mutect2, varscan2
- TENT2 | c.49C>T p.Q17* | Nonsense Mutation (SNP) | VAF 61/144 reads (42%) | catalogued as COSV99706140; called by muse, mutect2, varscan2
- TFG | c.284G>A p.R95K | Missense Mutation (SNP) | VAF 54/91 reads (59%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.899); catalogued as rs1329508587, COSV53748764; called by muse, mutect2, varscan2
- TG | c.5149C>G p.L1717V | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.187); catalogued as COSV55076273; called by muse, mutect2, varscan2
- THEMIS2 | c.1897G>A p.E633K | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61077742; called by muse, mutect2, varscan2
- THOC1 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as rs1433937819, COSV55274117; called by muse, mutect2, varscan2
- THOP1 | c.283C>T p.R95W | Missense Mutation (SNP) | VAF 99/189 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs764098478, COSV57018730; called by muse, mutect2, varscan2
- TJP2 | c.474G>C p.R158S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.05); catalogued as COSV55266758; called by muse, mutect2
- TLDC2 | c.178G>C p.E60Q | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV54114342; called by muse, mutect2, varscan2
- TLR2 | c.2093A>G p.K698R | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.949); catalogued as rs1381150145, COSV104390161, COSV52606338; called by muse, mutect2, varscan2
- TMC1 | c.1348C>T p.L450F | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs768579412, COSV52775402; called by muse, mutect2, varscan2
- TMC5 | c.694C>G p.Q232E | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.026); catalogued as COSV66866123; called by muse, mutect2, varscan2
- TMEM131 | c.1834G>C p.E612Q | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.8); PolyPhen benign (0.018); catalogued as COSV51775921; called by muse, mutect2, varscan2
- TMEM132E | c.2350C>T p.P784S (on ENST00000321639; = p.P874S on NM_001304438.2) | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.344); catalogued as rs1218648789, COSV58697027; called by muse, mutect2, varscan2
- TMEM87A | c.167G>C p.G56A | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.369); catalogued as COSV56197856; called by muse, mutect2, varscan2
- TMF1 | c.1942G>A p.E648K | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.627); catalogued as rs1253045731, COSV68374309; called by muse, mutect2, varscan2
- TNRC6C | c.1575C>A p.D525E | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs1292332137, COSV56945250; called by muse, mutect2, varscan2
- TOX2 | c.608C>T p.P203L (on ENST00000358131 / NM_001098798.2; = p.P152L on NM_032883.3) | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs559758657, COSV57884783; called by muse, varscan2
- TOX3 | c.1591C>T p.R531W | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs921473080, COSV54866125; called by muse, mutect2, varscan2
- TP53I11 | c.25C>G p.L9V | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57533070; called by muse, mutect2, varscan2
- TPO | c.74G>C p.R25T | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as COSV61101994; called by muse, mutect2, varscan2
- TPR | c.5728G>T p.E1910* | Nonsense Mutation (SNP) | VAF 20/55 reads (36%) | catalogued as COSV100823517, COSV66605386; called by muse, mutect2, varscan2
- TRANK1 | c.1747G>C p.E583Q | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs1381190799, COSV57150223; called by muse, mutect2, varscan2
- TRAPPC10 | c.1336G>T p.E446* | Nonsense Mutation (SNP) | VAF 11/47 reads (23%) | catalogued as COSV99378041; called by muse, mutect2, varscan2
- TRIM13 | c.384C>G p.F128L | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.191); catalogued as COSV53949556; called by muse, mutect2, varscan2
- TRIM24 | c.676C>T p.H226Y | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58969941, COSV58972426; called by muse, mutect2, varscan2
- TRIM47 | c.1733C>T p.S578F | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as COSV54668325; called by muse, mutect2, varscan2
- TRIO | c.8889C>G p.I2963M | Missense Mutation (SNP) | VAF 41/80 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as COSV59990128; called by muse, mutect2, varscan2
- TRMT1 | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55565692; called by muse, mutect2, varscan2
- TSC22D2 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1316590561, COSV62622620; called by muse, mutect2, varscan2
- TSR1 | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs144223722; called by muse, mutect2, varscan2
- TTN | c.98781G>A p.M32927I (on ENST00000591111; = p.M25503I on NM_003319.4) | Missense Mutation (SNP) | VAF 38/70 reads (54%) | PolyPhen probably damaging (0.961); catalogued as COSV60062741; called by muse, mutect2, varscan2
- TUT1 | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.24); catalogued as rs201443323, COSV53470046; called by muse, mutect2, varscan2
- TUT7 | c.4323G>C p.K1441N | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV52895714; called by muse, mutect2, varscan2
- UBA7 | c.1777G>T p.D593Y | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV61092213; called by muse, mutect2, varscan2
- ULK1 | c.1436C>T p.S479L | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.45); catalogued as rs759999368, COSV100416409; called by muse, varscan2
- ULK2 | c.1099G>A p.D367N | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as COSV64445781; called by muse, mutect2, varscan2
- ULK4 | c.45G>C p.K15N | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as rs1414521334, COSV57208976, COSV57215376; called by muse, mutect2, varscan2
- UNC13C | c.4391C>T p.S1464F | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1244046354, COSV99509758; called by muse, mutect2, varscan2
- USF3 | c.3245G>C p.R1082T | Missense Mutation (SNP) | VAF 57/102 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as COSV57072702; called by muse, mutect2, varscan2
- USH2A | c.14416G>A p.E4806K | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56369702; called by muse, mutect2, varscan2
- USH2A | c.4465C>T p.P1489S | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as COSV56369722; called by muse, mutect2, varscan2
- USP28 | c.2659-1G>C p.X887_splice | Splice Site (SNP) | VAF 19/52 reads (37%) | catalogued as COSV50162915, COSV50164042; called by muse, mutect2, varscan2
- USP42 | c.191C>G p.S64W | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs201800019, COSV100083812; called by muse, varscan2
- USP47 | c.1930-1G>A p.X644_splice (on ENST00000399455 / NM_001372095.1; = p.X556_splice on NM_017944.4 and 3 other RefSeq transcripts) | Splice Site (SNP) | VAF 16/35 reads (46%) | catalogued as COSV60463784; called by muse, mutect2, varscan2
- USP48 | c.1678G>C p.E560Q | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.68); PolyPhen benign (0.005); catalogued as COSV57610079; called by muse, varscan2
- VEGFD | c.456C>G p.I152M | Missense Mutation (SNP) | VAF 76/81 reads (94%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV52909613, COSV52909638; called by muse, mutect2, varscan2
- VRTN | c.1441G>C p.E481Q | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.076); catalogued as COSV56441053; called by muse, mutect2, varscan2
- VRTN | c.1616C>T p.S539F | Missense Mutation (SNP) | VAF 49/97 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV56441063; called by muse, mutect2, varscan2
- VWF | c.4838C>G p.S1613C | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54616268, COSV54620457; called by muse, mutect2, varscan2
- WDR81 | c.4300C>T p.Q1434* (on ENST00000409644 / NM_001163809.2; = p.Q383* on NM_152348.4) | Nonsense Mutation (SNP) | VAF 27/47 reads (57%) | catalogued as rs549804944, COSV100488378; called by muse, mutect2, varscan2
- WWC1 | c.253C>T p.R85* | Nonsense Mutation (SNP) | VAF 5/38 reads (13%) | catalogued as rs1193196849, COSV54657127; called by muse, mutect2, varscan2
- XIRP1 | c.4685C>T p.S1562F | Missense Mutation (SNP) | VAF 56/92 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as COSV61138502; called by muse, mutect2, varscan2
- YES1 | c.821G>A p.R274Q | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs752661671, COSV58848438; called by muse, mutect2, varscan2
- YPEL5 | c.100C>G p.R34G | Missense Mutation (SNP) | VAF 39/82 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.625); catalogued as COSV54395117, COSV54395316; called by muse, mutect2, varscan2
- ZBTB16 | c.298G>C p.D100H | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV60093122; called by muse, mutect2, varscan2
- ZC3H12A | c.131C>T p.S44L | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as rs140377627; called by muse, mutect2, varscan2
- ZCWPW1 | c.50G>C p.R17T | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as COSV61248516, COSV61249001; called by muse, mutect2
- ZEB1 | c.993G>C p.K331N | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100314268, COSV58043976, COSV58052245; called by muse, mutect2, varscan2
- ZFHX3 | c.1292C>T p.S431L | Missense Mutation (SNP) | VAF 40/142 reads (28%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.554); catalogued as COSV51718884; called by muse, mutect2, varscan2
- ZFP30 | c.781C>T p.Q261* | Nonsense Mutation (SNP) | VAF 64/91 reads (70%) | catalogued as COSV100665754, COSV100665803; called by muse, mutect2, varscan2
- ZGRF1 | c.1964A>G p.Y655C | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1378205247, COSV52200562, COSV52203464; called by muse, mutect2, varscan2
- ZNF180 | c.243C>A p.F81L | Missense Mutation (SNP) | VAF 64/102 reads (63%) | SIFT tolerated (0.12); PolyPhen benign (0.442); catalogued as COSV55421232; called by muse, mutect2
- ZNF43 | c.495G>T p.K165N | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.88); catalogued as COSV61683997; called by muse, mutect2, varscan2
- ZNF445 | c.140A>T p.N47I | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV68538874; called by muse, mutect2, varscan2
- ZNF496 | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.086); catalogued as rs1365347607, COSV54177190; called by muse, mutect2, varscan2
- ZNF530 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 112/184 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as rs1450720925, COSV60531566; called by muse, mutect2, varscan2
- ZNF607 | c.1735C>G p.H579D | Missense Mutation (SNP) | VAF 29/47 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67696882; called by muse, mutect2, varscan2
- ZNF665 | c.349G>A p.E117K (on ENST00000600412; = p.E182K on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 64/154 reads (42%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.848); catalogued as COSV67215123; called by muse, mutect2, varscan2
- ZNF783 | c.439G>A p.D147N | Missense Mutation (SNP) | VAF 78/165 reads (47%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.641); catalogued as COSV65185444; called by muse, mutect2, varscan2
- ZNF816-ZNF321P | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 50/228 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.398); catalogued as COSV58349500, COSV99040303; called by muse, mutect2, varscan2
- ZNF831 | c.3012C>G p.I1004M | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.215); catalogued as COSV100926216, COSV64040255; called by muse, mutect2, varscan2
- ZNF831 | c.3128C>T p.S1043L | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV64040260; called by muse, mutect2, varscan2
- ZNF846 | c.1276G>C p.E426Q | Missense Mutation (SNP) | VAF 52/95 reads (55%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV67412113; called by muse, mutect2, varscan2
- ZSWIM2 | c.751G>T p.E251* | Nonsense Mutation (SNP) | VAF 24/38 reads (63%) | catalogued as rs376901560, COSV99719772; called by muse, mutect2, varscan2
- AKAP6 | c.1769_1771del p.N590del | In Frame Del (DEL) | VAF 14/60 reads (23%) | called by pindel, varscan2
- FCGBP | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- IGKV6D-21 | c.43C>T p.P15S | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated (0.5); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- LPIN2 | c.1455del p.E486Kfs*20 | Frame Shift Del (DEL) | VAF 6/23 reads (26%) | called by mutect2, pindel
- MFHAS1 | c.2651dup p.Y884* | Nonsense Mutation (INS) | VAF 17/89 reads (19%) | called by mutect2, pindel, varscan2
- MYO19 | c.1714C>G p.P572A | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.539); called by muse, mutect2, varscan2
- PCDHGB5 | c.1696G>C p.D566H | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- PLA2G15 | c.725C>T p.S242L | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2
- SCN8A | c.4824del p.K1608Nfs*23 | Frame Shift Del (DEL) | VAF 67/245 reads (27%) | called by mutect2, pindel, varscan2
- SPATA31A1 | c.3613G>A p.E1205K | Missense Mutation (SNP) | VAF 130/199 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- STAG2 | c.2609_2619del p.K870Ifs*21 | Frame Shift Del (DEL) | VAF 12/18 reads (67%) | called by mutect2, varscan2
- TRGV9 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- AADACL4 | c.937C>T p.L313= | Silent (SNP) | VAF 42/140 reads (30%) | catalogued as COSV66106292; called by muse, mutect2, varscan2
- AARS1 | c.1902C>G p.L634= | Silent (SNP) | VAF 28/105 reads (27%) | catalogued as COSV55747420; called by muse, mutect2, varscan2
- ABCB1 | c.1536T>C p.F512= | Silent (SNP) | VAF 35/132 reads (27%) | catalogued as COSV55951298; called by muse, mutect2, varscan2
- ABCC1 | c.3282C>T p.F1094= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV60685924; called by muse, mutect2, varscan2
- ABCC8 | c.603G>A p.P201= | Silent (SNP) | VAF 17/34 reads (50%) | catalogued as rs765113879, COSV56850530, COSV56859295; called by muse, mutect2, varscan2
- ABCG8 | c.1035C>G p.L345= | Silent (SNP) | VAF 27/60 reads (45%) | catalogued as COSV55393296; called by muse, mutect2, varscan2
- ACP7 | c.726C>T p.F242= | Silent (SNP) | VAF 43/58 reads (74%) | catalogued as COSV58699342; called by muse, mutect2, varscan2
- ADAMTS19 | c.3231C>G p.V1077= | Silent (SNP) | VAF 62/147 reads (42%) | catalogued as COSV50747923; called by muse, mutect2, varscan2
- ADAP2 | c.762G>A p.R254= | Silent (SNP) | VAF 23/52 reads (44%) | catalogued as COSV58295945; called by muse, mutect2, varscan2
- AGO1 | c.930C>T p.F310= | Silent (SNP) | VAF 40/70 reads (57%) | catalogued as COSV100940882, COSV64595284; called by muse, mutect2, varscan2
- ALDH3A1 | c.537G>A p.E179= | Silent (SNP) | VAF 31/52 reads (60%) | catalogued as COSV56735295; called by muse, mutect2, varscan2
- AMER3 | c.795G>C p.L265= | Silent (SNP) | VAF 28/42 reads (67%) | catalogued as COSV58466768; called by muse, mutect2, varscan2
- ANK3 | c.12153G>A p.T4051= | Silent (SNP) | VAF 25/106 reads (24%) | catalogued as rs1190946768, COSV55057983; called by muse, mutect2, varscan2
- ANKRD11 | c.2337G>A p.K779= | Silent (SNP) | VAF 33/76 reads (43%) | catalogued as rs1348777057, COSV56361014; called by muse, mutect2, varscan2
- ANPEP | c.705C>T p.I235= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as rs753057297, COSV55591517; called by muse, mutect2, varscan2
- ATP2A2 | c.2847C>G p.V949= | Silent (SNP) | VAF 60/123 reads (49%) | catalogued as COSV57875418; called by muse, mutect2, varscan2
- BID | c.663G>A p.V221= (on ENST00000317361 / NM_197966.2; = p.V175= on NM_001196.4) | Silent (SNP) | VAF 30/62 reads (48%) | catalogued as COSV58006844; called by muse, varscan2
- BLM | c.3231G>C p.V1077= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as COSV61924135, COSV61925695; called by muse, mutect2, varscan2
- BPNT2 | c.162C>T p.A54= | Silent (SNP) | VAF 4/10 reads (40%) | called by muse, varscan2
- C19orf47 | c.1011G>T p.R337= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as rs1305764522, COSV63509074; called by muse, mutect2, varscan2
- CALCR | c.1389G>A p.L463= (on ENST00000649521 / NM_001164737.2; = p.L447= on NM_001742.4) | Silent (SNP) | VAF 82/171 reads (48%) | catalogued as COSV64005901, COSV64008220; called by muse, mutect2, varscan2
- CAPN1 | c.372C>T p.L124= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV54198645; called by muse, mutect2, varscan2
- CARMIL2 | c.1800C>T p.V600= | Silent (SNP) | VAF 30/60 reads (50%) | catalogued as rs1487573653, COSV58026331; called by muse, mutect2, varscan2
- CCDC88B | c.2979G>A p.E993= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as rs1259202713, COSV100104846, COSV57267309; called by muse, mutect2
- CD33 | c.1094G>A p.*365= | Silent (SNP) | VAF 43/74 reads (58%) | catalogued as COSV99219958; called by muse, mutect2, varscan2
- CDCA2 | c.1404C>G p.L468= | Silent (SNP) | VAF 84/181 reads (46%) | catalogued as COSV57945914; called by muse, mutect2, varscan2
- CDK8 | c.1251C>T p.I417= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as rs780824420, COSV67420775; called by muse, mutect2, varscan2
- CECR2 | c.276C>T p.L92= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as rs772234587, COSV52841169; called by muse, mutect2, varscan2
- CELSR1 | c.2040G>C p.V680= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV53090224; called by muse, mutect2
- CETP | c.900C>T p.L300= | Silent (SNP) | VAF 22/39 reads (56%) | catalogued as COSV52362598; called by muse, mutect2, varscan2
- CHMP7 | c.855C>G p.L285= | Silent (SNP) | VAF 48/123 reads (39%) | catalogued as COSV57532960; called by muse, mutect2, varscan2
- CHST15 | c.843C>T p.F281= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV60562287; called by mutect2, varscan2
- CKAP2 | c.90C>G p.L30= | Silent (SNP) | VAF 49/103 reads (48%) | catalogued as COSV51622117; called by muse, mutect2, varscan2
- CLOCK | c.1251C>T p.L417= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as COSV59401905; called by muse, mutect2, varscan2
- COL5A1 | c.675C>G p.L225= | Silent (SNP) | VAF 46/100 reads (46%) | catalogued as rs531830334, COSV65668950; called by muse, mutect2, varscan2
- CP | c.1356C>T p.V452= | Silent (SNP) | VAF 46/78 reads (59%) | catalogued as COSV52830659; called by muse, mutect2, varscan2
- CPNE6 | c.1368C>T p.I456= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as rs770389348, COSV53744121; called by muse, mutect2, varscan2
- CRY1 | c.942C>A p.I314= | Silent (SNP) | VAF 32/63 reads (51%) | catalogued as COSV50482845; called by muse, mutect2, varscan2
- CSMD2 | c.8331G>A p.P2777= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as rs141501015, COSV53923729; called by muse, mutect2, varscan2
- CTAGE1 | c.1542C>T p.L514= | Silent (SNP) | VAF 33/116 reads (28%) | catalogued as COSV66943431; called by muse, mutect2, varscan2
- DENND4C | c.1716T>A p.S572= | Silent (SNP) | VAF 6/120 reads (5%) | catalogued as COSV66822137; called by muse, mutect2
- DEPDC4 | c.471C>G p.L157= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as COSV54553668; called by muse, mutect2, varscan2
- DNM2 | c.1524G>A p.K508= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as COSV58961768; called by muse, varscan2
- DPT | c.402C>G p.R134= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as COSV63189972; called by muse, mutect2, varscan2
- DSPP | c.504C>T p.G168= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as rs539814032, COSV56810430; called by muse, mutect2, varscan2
- E2F7 | c.1005C>T p.L335= | Silent (SNP) | VAF 42/133 reads (32%) | catalogued as COSV59739976; called by muse, mutect2, varscan2
- ECM1 | c.1467G>C p.L489= | Silent (SNP) | VAF 75/176 reads (43%) | catalogued as COSV60872998; called by muse, mutect2, varscan2
- EIF4EBP2 | c.72C>T p.I24= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs772752087, COSV100946989; called by muse, varscan2
- EIF6 | c.174C>T p.I58= | Silent (SNP) | VAF 42/112 reads (38%) | catalogued as COSV65583042; called by muse, mutect2, varscan2
- ELOVL2 | c.225C>T p.I75= | Silent (SNP) | VAF 38/48 reads (79%) | catalogued as COSV100675959, COSV61155222; called by muse, mutect2, varscan2
- EMC3 | c.69C>T p.I23= | Silent (SNP) | VAF 22/73 reads (30%) | catalogued as COSV55278162; called by muse, mutect2, varscan2
- EMX2 | c.372C>A p.I124= | Silent (SNP) | VAF 36/61 reads (59%) | catalogued as COSV71294577; called by muse, mutect2, varscan2
- EPS8L2 | c.873G>A p.K291= | Silent (SNP) | VAF 15/27 reads (56%) | catalogued as COSV59347934; called by muse, mutect2, varscan2
- FAT2 | c.12342C>T p.L4114= | Silent (SNP) | VAF 54/124 reads (44%) | catalogued as COSV55819743; called by muse, mutect2
- FCGBP | c.11820C>G p.L3940= | Silent (SNP) | VAF 7/44 reads (16%) | called by muse, mutect2, varscan2
- FCGBP | c.7971G>A p.Q2657= | Silent (SNP) | VAF 8/118 reads (7%) | called by muse, mutect2
- FCRLB | c.831G>A p.R277= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as COSV100396042; called by muse, mutect2
- FGF14 | c.312C>T p.F104= | Silent (SNP) | VAF 117/144 reads (81%) | catalogued as rs771804837, COSV65943848; called by muse, mutect2, varscan2
- FGFBP1 | c.318C>G p.L106= | Silent (SNP) | VAF 49/89 reads (55%) | catalogued as rs757775564, COSV52586488; called by muse, mutect2, varscan2
- FGFR1 | c.1047C>T p.L349= (on ENST00000447712 / NM_023110.3; = p.L347= on NM_015850.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as COSV58334492; called by muse, mutect2, varscan2
- FLG | c.3273G>A p.Q1091= | Silent (SNP) | VAF 190/493 reads (39%) | catalogued as COSV64241846; called by muse, mutect2, varscan2
- FLNA | c.3699C>T p.I1233= | Silent (SNP) | VAF 42/47 reads (89%) | catalogued as COSV61043030, COSV61045599; called by muse, mutect2, varscan2
- FOXA1 | c.15G>A p.V5= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as rs777922164, COSV51645842; called by muse, mutect2, varscan2
- FRMPD1 | c.3744C>G p.V1248= | Silent (SNP) | VAF 35/42 reads (83%) | catalogued as COSV66700426; called by muse, mutect2, varscan2
- GAPVD1 | c.1023G>C p.L341= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as COSV52923016; called by muse, mutect2, varscan2
- GCLC | c.978C>T p.I326= (on ENST00000643939; = p.I324= on NM_001498.4) | Silent (SNP) | VAF 24/32 reads (75%) | catalogued as COSV57595559; called by muse, mutect2, varscan2
- GOLGB1 | c.618C>G p.L206= | Silent (SNP) | VAF 36/141 reads (26%) | catalogued as rs371481231, COSV61465878; called by muse, mutect2, varscan2
- GRK5 | c.384G>A p.Q128= | Silent (SNP) | VAF 36/191 reads (19%) | catalogued as rs765439908, COSV64866414; called by muse, mutect2, varscan2
- GRM7 | c.2589C>T p.F863= | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as COSV63143396; called by muse, mutect2, varscan2
- GRPEL1 | c.18G>T p.V6= | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as COSV99380498; called by muse, mutect2
- GSTM5 | c.153C>T p.F51= | Silent (SNP) | VAF 18/112 reads (16%) | catalogued as COSV56658088; called by muse, mutect2, varscan2
- HEATR5B | c.4770G>C p.L1590= | Silent (SNP) | VAF 37/68 reads (54%) | catalogued as rs144736173; called by muse, mutect2, varscan2
- HELZ2 | c.2034C>T p.L678= (on ENST00000467148 / NM_001037335.2; = p.L109= on NM_033405.3) | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as rs762758254, COSV64409667; called by muse, varscan2
- HERC2 | c.13329C>T p.V4443= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as rs769323259, COSV55323787; called by muse, mutect2, varscan2
- HOXC8 | c.327G>A p.V109= | Silent (SNP) | VAF 71/337 reads (21%) | catalogued as rs777416892, COSV50001340; called by muse, varscan2
- IGF2BP1 | c.27C>T p.L9= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as COSV51731377; called by muse, mutect2, varscan2
- IGHG1 | c.930G>A p.V310= | Silent (SNP) | VAF 33/91 reads (36%) | called by muse, mutect2, varscan2
- IGLV1-36 | c.246C>T p.F82= | Silent (SNP) | VAF 48/177 reads (27%) | called by muse, mutect2, varscan2
- INVS | c.2631T>A p.T877= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as COSV52442021; called by muse, mutect2, varscan2
- ITPR2 | c.4221G>A p.V1407= | Silent (SNP) | VAF 13/135 reads (10%) | catalogued as COSV67269337; called by muse, mutect2
- JOSD1 | c.561G>A p.V187= | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as rs1437501576, COSV53265648; called by muse, mutect2, varscan2
- KCND2 | c.294C>T p.F98= | Silent (SNP) | VAF 59/182 reads (32%) | catalogued as COSV58580246; called by muse, mutect2, varscan2
- KCNH3 | c.351G>A p.K117= | Silent (SNP) | VAF 38/227 reads (17%) | catalogued as COSV57790811, COSV57791820; called by muse, mutect2, varscan2
- KCNK1 | c.591C>T p.F197= | Silent (SNP) | VAF 70/138 reads (51%) | catalogued as COSV64035105; called by muse, mutect2, varscan2
- KIF16B | c.849G>A p.G283= | Silent (SNP) | VAF 35/82 reads (43%) | catalogued as COSV61706223; called by muse, mutect2, varscan2
- KIF18A | c.1323G>T p.L441= | Silent (SNP) | VAF 28/140 reads (20%) | catalogued as COSV54181331, COSV54183271; called by muse, mutect2, varscan2
- KIF20B | c.1488C>T p.V496= | Silent (SNP) | VAF 57/113 reads (50%) | catalogued as COSV53307218; called by muse, mutect2, varscan2
- KMT2D | c.5841C>G p.L1947= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV56439676; called by muse, mutect2, varscan2
- KPNA1 | c.1245G>A p.Q415= | Silent (SNP) | VAF 30/130 reads (23%) | catalogued as rs1380546684, COSV60268985; called by muse, mutect2, varscan2
- KRT6A | c.1305G>A p.Q435= | Silent (SNP) | VAF 56/147 reads (38%) | catalogued as COSV58105156; called by muse, mutect2, varscan2
- KRT7 | c.117C>G p.L39= | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as rs1043576587, COSV100081244; called by muse, mutect2
- LAMA3 | c.8607G>A p.L2869= (on ENST00000313654 / NM_198129.4; = p.L1260= on NM_000227.6) | Silent (SNP) | VAF 72/133 reads (54%) | catalogued as COSV52534702, COSV52539881; called by muse, mutect2, varscan2
- LAT | c.546C>T p.L182= | Silent (SNP) | VAF 37/61 reads (61%) | catalogued as rs777798581, COSV57954730; called by muse, mutect2, varscan2
- LILRB1 | c.249C>A p.L83= (on ENST00000427581; = p.L47= on NM_006669.6) | Silent (SNP) | VAF 57/158 reads (36%) | catalogued as COSV100207273, COSV61117949; called by muse, mutect2, varscan2
- LMOD2 | c.739C>T p.L247= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV71755642; called by muse, mutect2, varscan2
- LRFN5 | c.438C>G p.V146= | Silent (SNP) | VAF 24/73 reads (33%) | catalogued as COSV53256468; called by muse, mutect2, varscan2
- LRFN5 | c.645C>T p.L215= | Silent (SNP) | VAF 19/62 reads (31%) | catalogued as COSV53242191, COSV53256475; called by muse, mutect2, varscan2
- LRIT3 | c.1278G>A p.L426= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as COSV59985284; called by muse, mutect2, varscan2
- LRP1B | c.6549G>C p.L2183= | Silent (SNP) | VAF 5/114 reads (4%) | catalogued as COSV101255496, COSV67220586; called by muse, mutect2
- LRRK1 | c.1071G>A p.L357= | Silent (SNP) | VAF 25/101 reads (25%) | catalogued as rs1226699333, COSV52611674; called by muse, mutect2, varscan2
- LZTR1 | c.660G>A p.Q220= | Silent (SNP) | VAF 22/82 reads (27%) | catalogued as COSV53147533; called by muse, varscan2
- MAB21L1 | c.369C>T p.L123= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV59784411; called by muse, mutect2, varscan2
- MAPT | c.660G>C p.L220= (on ENST00000262410 / NM_001377265.1; = p.L145= on NM_016835.4) | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs753846431, COSV99289507; called by muse, mutect2, varscan2
- MB | c.459G>A p.Q153= | Silent (SNP) | VAF 4/56 reads (7%) | catalogued as COSV100704665; called by muse, mutect2
- METTL2A | c.1074G>A p.L358= | Silent (SNP) | VAF 70/197 reads (36%) | catalogued as COSV61044532; called by muse, mutect2, varscan2
- MMP25 | c.516C>T p.I172= | Silent (SNP) | VAF 27/49 reads (55%) | catalogued as rs1045419503, COSV60679563; called by muse, mutect2, varscan2
- MRGPRD | c.60G>C p.G20= | Silent (SNP) | VAF 23/73 reads (32%) | catalogued as COSV58423157; called by muse, mutect2, varscan2
- MTHFR | c.1576C>T p.L526= | Silent (SNP) | VAF 35/100 reads (35%) | catalogued as COSV57172574; called by muse, mutect2, varscan2
- MYEF2 | c.1156C>T p.L386= | Silent (SNP) | VAF 20/97 reads (21%) | catalogued as COSV51047646; called by muse, mutect2, varscan2
- MYH14 | c.2946G>A p.A982= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as rs372701728; called by muse, varscan2
- NAPSA | c.1029C>T p.V343= | Silent (SNP) | VAF 59/82 reads (72%) | catalogued as COSV53797476; called by muse, mutect2, varscan2
- NBN | c.120G>C p.S40= | Silent (SNP) | VAF 61/138 reads (44%) | catalogued as rs774989816, COSV55373096, COSV99619967; ClinVar: likely benign; called by muse, mutect2, varscan2
- NCOA7 | c.726G>A p.V242= | Silent (SNP) | VAF 103/138 reads (75%) | catalogued as COSV57655442; called by muse, mutect2, varscan2
- NDST1 | c.1527C>A p.I509= | Silent (SNP) | VAF 46/120 reads (38%) | catalogued as COSV55787293; called by muse, mutect2, varscan2
- NICN1 | c.30G>A p.V10= | Silent (SNP) | VAF 30/49 reads (61%) | catalogued as COSV56474601; called by muse, mutect2, varscan2
- NLRC5 | c.3495G>A p.L1165= | Silent (SNP) | VAF 188/334 reads (56%) | catalogued as rs764467616, COSV52655107; called by muse, mutect2, varscan2
- NOX4 | c.27C>T p.L9= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as rs769797957, COSV54451320; called by muse, mutect2, varscan2
- NR2F6 | c.300C>T p.I100= | Silent (SNP) | VAF 28/85 reads (33%) | catalogued as rs1451835409, COSV52243815, COSV99360319; called by muse, mutect2, varscan2
- OASL | c.54C>T p.F18= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as rs934147632, COSV57478333; called by muse, mutect2, varscan2
- OR2T8 | c.96C>T p.I32= | Silent (SNP) | VAF 40/89 reads (45%) | catalogued as rs369748850; called by muse, mutect2, varscan2
- OR4X2 | c.63G>A p.V21= | Silent (SNP) | VAF 15/85 reads (18%) | catalogued as COSV56583364; called by muse, mutect2
- OR6M1 | c.924G>A p.L308= | Silent (SNP) | VAF 51/99 reads (52%) | catalogued as COSV58433588, COSV58434602; called by muse, mutect2, varscan2
- P4HA3 | c.942C>G p.L314= | Silent (SNP) | VAF 24/81 reads (30%) | catalogued as COSV59041883; called by muse, mutect2, varscan2
- PADI3 | c.1512G>A p.Q504= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV100968369; called by muse, mutect2
- PALLD | c.1128C>T p.F376= | Silent (SNP) | VAF 39/69 reads (57%) | catalogued as COSV54980616; called by muse, mutect2, varscan2
- PANK1 | c.960C>T p.F320= (on ENST00000307534 / NM_148977.2; = p.F95= on NM_138316.4) | Silent (SNP) | VAF 32/55 reads (58%) | catalogued as COSV56808154; called by muse, mutect2, varscan2
- PAPSS1 | c.1707G>A p.K569= | Silent (SNP) | VAF 53/97 reads (55%) | catalogued as COSV54489158, COSV99492495; called by muse, mutect2, varscan2
- PC | c.2697G>A p.Q899= | Silent (SNP) | VAF 20/41 reads (49%) | catalogued as COSV58992721; called by muse, mutect2, varscan2
- PCDH12 | c.2313G>A p.Q771= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV51521434; called by muse, mutect2, varscan2
- PCDHB13 | c.1023G>A p.V341= | Silent (SNP) | VAF 109/259 reads (42%) | catalogued as rs1554287804, COSV53396550; called by muse, mutect2, varscan2
- PDGFRA | c.66C>T p.L22= | Silent (SNP) | VAF 77/125 reads (62%) | catalogued as COSV57268021, COSV99956721; called by muse, mutect2, varscan2
- PDPR | c.714C>G p.V238= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as COSV55351864; called by muse, mutect2, varscan2
- PDZRN4 | c.2955C>T p.I985= (on ENST00000402685 / NM_001164595.2; = p.I727= on NM_013377.4) | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as COSV54201655; called by muse, mutect2, varscan2
- PGAM2 | c.192C>T p.I64= | Silent (SNP) | VAF 19/62 reads (31%) | catalogued as COSV51977845; called by muse, mutect2, varscan2
- PHOX2B | c.399G>A p.L133= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as rs1372476793, COSV56929531; called by muse, mutect2, varscan2
- PITPNM2 | c.1335G>A p.K445= | Silent (SNP) | VAF 40/87 reads (46%) | catalogued as COSV54900751; called by muse, mutect2, varscan2
- PNPO | c.564C>G p.V188= (on ENST00000225573; = p.V231= on NM_018129.4) | Silent (SNP) | VAF 52/118 reads (44%) | catalogued as COSV56666435; called by muse, mutect2, varscan2
- POLRMT | c.1512G>A p.L504= | Silent (SNP) | VAF 3/11 reads (27%) | catalogued as COSV101646086; called by muse, mutect2
- PRAMEF18 | c.711C>T p.L237= | Silent (SNP) | VAF 127/541 reads (23%) | called by muse, mutect2, varscan2
- PRM2 | c.6C>T p.V2= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV54113213, COSV99617756; called by muse, mutect2
- PROK1 | c.33C>T p.L11= | Silent (SNP) | VAF 23/61 reads (38%) | catalogued as COSV54764953; called by muse, mutect2, varscan2
- PSMC2 | c.504G>A p.E168= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as rs746034947, COSV53007461; called by muse, mutect2, varscan2
- PSTPIP1 | c.804C>T p.F268= | Silent (SNP) | VAF 21/39 reads (54%) | catalogued as COSV51200004; called by muse, mutect2, varscan2
- PTPRM | c.342C>T p.L114= | Silent (SNP) | VAF 20/82 reads (24%) | catalogued as COSV59849027; called by muse, varscan2
- RBX1 | c.30G>C p.P10= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV53429571, COSV99345387; called by muse, mutect2
- RELCH | c.9G>A p.A3= | Silent (SNP) | VAF 56/108 reads (52%) | catalogued as rs1315310482, COSV56885568; called by muse, mutect2, varscan2
- RFPL3 | c.678C>G p.L226= (on ENST00000249007 / NM_001098535.1; = p.L197= on NM_006604.2) | Silent (SNP) | VAF 35/78 reads (45%) | catalogued as COSV50748957; called by muse, mutect2, varscan2
- RHOBTB1 | c.1629C>G p.L543= | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as COSV61958605; called by muse, mutect2, varscan2
- RND1 | c.600C>T p.V200= | Silent (SNP) | VAF 44/82 reads (54%) | catalogued as rs1352922138, COSV59045134; called by muse, mutect2, varscan2
- RNF145 | c.552C>G p.L184= (on ENST00000424310 / NM_001199383.2; = p.L212= on NM_144726.2) | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as COSV50866365; called by muse, mutect2, varscan2
- RPRD2 | c.174C>T p.I58= | Silent (SNP) | VAF 33/66 reads (50%) | catalogued as rs1305802723, COSV64816840; called by muse, mutect2, varscan2
- RRN3 | c.1425G>A p.L475= | Silent (SNP) | VAF 11/94 reads (12%) | catalogued as COSV99548551; called by muse, mutect2, varscan2
- RSPH14 | c.600C>T p.L200= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as COSV53268596; called by muse, mutect2, varscan2
- RWDD2B | c.153T>G p.P51= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as rs1363681842, COSV54501489; called by muse, mutect2, varscan2
- SART1 | c.1278C>T p.L426= | Silent (SNP) | VAF 81/153 reads (53%) | catalogued as rs201336410, COSV56711643; called by muse, mutect2, varscan2
- SBF2 | c.1200G>A p.E400= | Silent (SNP) | VAF 22/47 reads (47%) | catalogued as COSV56294007; called by muse, mutect2, varscan2
- SCRIB | c.291C>T p.I97= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as rs1431575231, COSV57586932; called by muse, mutect2, varscan2
- SEMA3C | c.1665G>C p.V555= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as COSV54841709, COSV54848150; called by muse, mutect2, varscan2
- SERPINB13 | c.969C>T p.S323= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as rs1384252179, COSV54028564; called by muse, mutect2, varscan2
- SHANK3 | c.4275G>A p.P1425= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as rs755891118, COSV53186625; called by muse, mutect2, varscan2
- SLC38A8 | c.480C>T p.V160= | Silent (SNP) | VAF 53/101 reads (52%) | catalogued as COSV55306569; called by muse, mutect2, varscan2
- SLCO3A1 | c.1899C>G p.L633= | Silent (SNP) | VAF 32/58 reads (55%) | catalogued as COSV59230122; called by muse, mutect2, varscan2
- SNAPC1 | c.78C>T p.F26= | Silent (SNP) | VAF 38/107 reads (36%) | catalogued as rs779195305, COSV53519963; called by muse, mutect2, varscan2
- SNTG1 | c.930G>A p.L310= | Silent (SNP) | VAF 74/172 reads (43%) | catalogued as COSV52443797; called by muse, mutect2, varscan2
- SORBS2 | c.1092C>T p.N364= | Silent (SNP) | VAF 41/86 reads (48%) | catalogued as rs772180081, COSV52999965; called by muse, mutect2, varscan2
- SPATA31D1 | c.4275C>T p.I1425= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs372313132; called by muse, mutect2, varscan2
- SPATA4 | c.729C>T p.L243= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as COSV54589945; called by muse, mutect2, varscan2
- SPTB | c.3885G>T p.L1295= | Silent (SNP) | VAF 85/163 reads (52%) | catalogued as COSV67631815; called by muse, mutect2, varscan2
- SRGAP3 | c.3225C>T p.G1075= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV64532218; called by muse, mutect2
- ST3GAL3 | c.1170C>A p.I390= (on ENST00000361392 / NM_174964.4; = p.I375= on NM_006279.5) | Silent (SNP) | VAF 48/152 reads (32%) | catalogued as COSV53511161; called by muse, mutect2, varscan2
- ST6GALNAC2 | c.480G>A p.L160= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV56571344; called by muse, mutect2, varscan2
- STIM2 | c.1966C>T p.L656= | Silent (SNP) | VAF 56/99 reads (57%) | catalogued as COSV52839053; called by muse, mutect2, varscan2
- STYXL2 | c.3330G>T p.G1110= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as COSV54805162, COSV99608813; called by muse, mutect2
- TACO1 | c.729G>A p.R243= | Silent (SNP) | VAF 61/162 reads (38%) | catalogued as COSV51975732; called by muse, mutect2, varscan2
- TBC1D4 | c.3714G>A p.L1238= | Silent (SNP) | VAF 150/207 reads (72%) | catalogued as COSV66489246; called by muse, mutect2, varscan2
- TBC1D4 | c.387C>T p.F129= | Silent (SNP) | VAF 117/161 reads (73%) | catalogued as COSV66489248; called by muse, mutect2, varscan2
- TBCD | c.1716C>T p.I572= | Silent (SNP) | VAF 40/89 reads (45%) | catalogued as COSV62801016; called by muse, mutect2, varscan2
- TGM2 | c.171C>T p.L57= | Silent (SNP) | VAF 18/25 reads (72%) | catalogued as COSV63930972, COSV63931613; called by muse, mutect2, varscan2
- THAP5 | c.594G>A p.E198= (on ENST00000415914 / NM_001130475.3; = p.E156= on NM_182529.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 48/82 reads (59%) | catalogued as rs1448111897, COSV50812116, COSV99974427; called by muse, mutect2, varscan2
- TMPRSS13 | c.1050C>A p.I350= | Silent (SNP) | VAF 3/23 reads (13%) | catalogued as COSV101471342, COSV101471370; called by muse, mutect2
- TNRC18 | c.4827C>A p.I1609= | Silent (SNP) | VAF 82/156 reads (53%) | catalogued as COSV68165497; called by muse, mutect2
- TRPM1 | c.2079G>A p.Q693= | Silent (SNP) | VAF 34/67 reads (51%) | catalogued as COSV56634582; called by muse, mutect2, varscan2
- UBB | c.357C>A p.L119= | Silent (SNP) | VAF 28/112 reads (25%) | catalogued as COSV56218747; called by muse, mutect2, varscan2
- UBR4 | c.7665C>T p.L2555= | Silent (SNP) | VAF 121/226 reads (54%) | catalogued as COSV64387021, COSV64389656; called by muse, mutect2, varscan2
- USP32 | c.3111C>T p.F1037= | Silent (SNP) | VAF 52/139 reads (37%) | catalogued as rs757907081, COSV56268933; called by muse, mutect2, varscan2
- USP37 | c.2172G>C p.L724= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as COSV51443467; called by muse, mutect2, varscan2
- USP48 | c.1746G>A p.L582= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as COSV57610065; called by muse, varscan2
- ZDHHC5 | c.591C>T p.F197= | Silent (SNP) | VAF 72/268 reads (27%) | catalogued as COSV54706679; called by muse, mutect2, varscan2
- ZFP42 | c.576G>A p.Q192= | Silent (SNP) | VAF 67/116 reads (58%) | catalogued as COSV58817415; called by muse, mutect2, varscan2
- ZIC1 | c.12C>T p.D4= | Silent (SNP) | VAF 5/9 reads (56%) | catalogued as COSV51558491; called by muse, mutect2, varscan2
- ZNF257 | c.159C>T p.I53= | Silent (SNP) | VAF 46/187 reads (25%) | catalogued as rs778115090, COSV71307480; called by muse, mutect2, varscan2
- ZNF277 | c.690G>A p.E230= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV62464329; called by muse, mutect2, varscan2
- ZNF335 | c.3069C>T p.I1023= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as COSV59817827; called by muse, mutect2, varscan2
- ZNF600 | c.1101C>T p.F367= | Silent (SNP) | VAF 128/234 reads (55%) | catalogued as rs769798542, COSV57742619; called by muse, mutect2, varscan2
- ZNF638 | c.3633G>A p.K1211= | Silent (SNP) | VAF 23/83 reads (28%) | catalogued as COSV52487231; called by muse, mutect2, varscan2
- ZNF648 | c.1416C>T p.G472= | Silent (SNP) | VAF 3/24 reads (13%) | catalogued as COSV60570786; called by muse, mutect2
- ZNF785 | c.600C>T p.F200= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV67876333; called by muse, mutect2
- ZZZ3 | c.2004C>A p.I668= | Silent (SNP) | VAF 32/115 reads (28%) | catalogued as COSV66232738, COSV66234454; called by muse, mutect2, varscan2
- ANXA13 | c.15+1523C>T | Intron (SNP) | VAF 33/92 reads (36%) | catalogued as rs1458009748, COSV51623367; called by muse, mutect2
- ANXA13 | c.15+1521C>T | Intron (SNP) | VAF 34/92 reads (37%) | catalogued as COSV51623373; called by muse, mutect2
- CHAT | c.287-420G>A | Intron (SNP) | VAF 32/67 reads (48%) | catalogued as COSV60325059; called by muse, mutect2, varscan2
- CLLU1 | n.882C>G | RNA (SNP) | VAF 10/76 reads (13%) | catalogued as COSV65903063; called by muse, mutect2, varscan2
- CLN5 | c.*472G>A | 3'UTR (SNP) | VAF 5/72 reads (7%) | catalogued as rs1262705264, COSV62918767; called by muse, mutect2
- CTNNAL1 | c.2140-28A>T | Intron (SNP) | VAF 12/38 reads (32%) | catalogued as COSV100336234; called by muse, mutect2, varscan2
- FAM21FP | n.211C>A | RNA (SNP) | VAF 31/73 reads (42%) | called by muse, mutect2, varscan2
- FBXO7 | c.122+252C>G | Intron (SNP) | VAF 10/38 reads (26%) | catalogued as rs1390649093, COSV56678068; called by muse, mutect2
- FEZ2 | c.904-2286G>A | Intron (SNP) | VAF 43/126 reads (34%) | catalogued as rs1272964881, COSV59906490; called by muse, mutect2, varscan2
- IGLV8OR8-1 | n.56C>G | RNA (SNP) | VAF 28/64 reads (44%) | called by muse, mutect2, varscan2
- MALAT1 | n.101G>A | RNA (SNP) | VAF 52/92 reads (57%) | catalogued as rs1235152301; called by muse, mutect2, varscan2
- MFRP | chr11:119346371 C>A | 5'Flank (SNP) | VAF 19/31 reads (61%) | catalogued as rs529716845, COSV100793277; called by muse, mutect2, varscan2
- N4BP2L2 | chr13:32442771 G>C | 3'Flank (SNP) | VAF 12/32 reads (38%) | catalogued as COSV62632929; called by muse, mutect2, varscan2
- PIK3C2B | c.934-1684C>T | Intron (SNP) | VAF 13/24 reads (54%) | catalogued as rs1348126529; called by muse, mutect2, varscan2
- PKD1L2 | n.341C>T | RNA (SNP) | VAF 11/25 reads (44%) | catalogued as rs981544359; called by muse, mutect2, varscan2
- PSG5 | c.431-3007G>A | Intron (SNP) | VAF 54/332 reads (16%) | catalogued as COSV100742516; called by muse, mutect2
- PTCD3 | c.-1G>C | 5'UTR (SNP) | VAF 12/38 reads (32%) | catalogued as COSV99605871; called by muse, mutect2, varscan2
- RARB | chr3:25596578 G>C | 3'Flank (SNP) | VAF 30/62 reads (48%) | catalogued as COSV51972130; called by muse, mutect2, varscan2
- RFX3 | c.1968+121A>G | Intron (SNP) | VAF 45/59 reads (76%) | catalogued as COSV56515348; called by muse, mutect2, varscan2
- RORA | c.197-25043C>T | Intron (SNP) | VAF 49/102 reads (48%) | catalogued as COSV55038879; called by muse, mutect2, varscan2
4 further variants in this file (0 protein-altering or splice-affecting, 0 silent, 4 other) are not listed here.
